Somatic mutation profile of tumor specimen TCGA-D3-A8GQ-06A (aliquot TCGA-D3-A8GQ-06A-11D-A372-08) from TCGA case TCGA-D3-A8GQ, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 68.1 years (24,884 days).
Specimen TCGA-D3-A8GQ-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 343a0128-8c5b-4007-a665-bbe5d77c624c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-D3-A8GQ-10A (Blood Derived Normal), aliquot TCGA-D3-A8GQ-10A-01D-A375-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/44b2cec3-018f-4d0e-9977-e1286409155f

The open-access MAF lists 1,726 somatic variants for this specimen: 1,108 protein-altering or splice-affecting, 574 silent, 44 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 1,004, Silent 574, Nonsense Mutation 59, Intron 20, Splice Site 19, Splice Region 16, Frame Shift Del 9, RNA 9, 5'UTR 5, 3'UTR 5, 3'Flank 4, Translation Start Site 1.

Variants (750 of 1,726; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CRB1 | c.1913C>T p.S638L | Missense Mutation (SNP) | VAF 45/253 reads (18%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs267598278, COSV66329373; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.182A>T p.Q61L | Missense Mutation (SNP) | VAF 69/125 reads (55%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SCN1A | c.2584C>T p.R862* (on ENST00000303395 / NM_001202435.3; = p.R851* on NM_006920.6 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 34/76 reads (45%) | catalogued as rs397514459, CM093370, CM116003, COSV57665384; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AARS2 | c.1051C>T p.R351C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766485554, COSV55116456; called by muse, mutect2, varscan2
- ABCB10 | c.944C>A p.A315D | Missense Mutation (SNP) | VAF 3/45 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100747846; called by muse, mutect2
- ABCB8 | c.2137G>A p.D713N (on ENST00000297504 / NM_001282291.2; = p.D696N on NM_007188.5) | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as rs1360671513, COSV99873766; called by muse, mutect2, varscan2
- ABCC12 | c.3224G>A p.R1075Q | Missense Mutation (SNP) | VAF 52/191 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as COSV60916197; called by muse, mutect2, varscan2
- ABCC12 | c.610G>A p.E204K | Missense Mutation (SNP) | VAF 53/167 reads (32%) | SIFT tolerated (0.23); PolyPhen benign (0.006); catalogued as COSV100252162; called by muse, mutect2, varscan2
- ABCC9 | c.836C>T p.P279L | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as COSV99684439; called by muse, mutect2, varscan2
- ABCG8 | c.1767G>A p.W589* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | catalogued as COSV99699416; called by muse, mutect2, varscan2
- ABHD13 | c.343C>T p.P115S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV101024040; called by muse, mutect2, varscan2
- ABI1 | c.718A>T p.S240C | Missense Mutation (SNP) | VAF 43/135 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.927); catalogued as rs1433322115, COSV100697722; called by muse, mutect2, varscan2
- ABI3BP | c.793G>A p.A265T | Missense Mutation (SNP) | VAF 18/85 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs764281790, COSV99425360; called by muse, mutect2, varscan2
- ABLIM2 | c.916G>A p.E306K | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99588962; called by muse, mutect2, varscan2
- ABRA | c.622G>A p.G208R | Missense Mutation (SNP) | VAF 44/178 reads (25%) | SIFT tolerated (0.26); PolyPhen benign (0.01); catalogued as COSV100357458; called by muse, mutect2, varscan2
- AC006059.2 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV59607272; called by muse, mutect2, varscan2
- AC100868.1 | c.1337G>A p.G446E | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.835); catalogued as COSV51845544, COSV99225242; called by muse, mutect2, varscan2
- ACACB | c.307C>T p.P103S | Missense Mutation (SNP) | VAF 32/140 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.014); catalogued as COSV100622314; called by muse, mutect2, varscan2
- ACACB | c.3943C>T p.P1315S | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100622317; called by muse, mutect2, varscan2
- ACAN | c.4532C>T p.S1511L | Missense Mutation (SNP) | VAF 28/121 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV100717038; called by muse, mutect2
- ACAN | c.7255G>C p.D2419H (on ENST00000560601 / NM_001369268.1; = p.D2343H on NM_001135.3) | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM090157, COSV100717039; called by muse, mutect2, varscan2
- ACD | c.1247C>T p.S416F (on ENST00000620338; = p.S327F on NM_022914.3) | Missense Mutation (SNP) | VAF 23/76 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); catalogued as COSV99537403; called by muse, mutect2, varscan2
- ACSF3 | c.1052T>C p.L351P | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs753012117, COSV100441082; called by muse, mutect2, varscan2
- ACSM2A | c.420G>A p.M140I (on ENST00000219054; = p.M61I on NM_001308169.2) | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV54584565; called by muse, mutect2, varscan2
- ACSM2A | c.967C>T p.L323F (on ENST00000219054; = p.L244F on NM_001308169.2) | Missense Mutation (SNP) | VAF 36/85 reads (42%) | SIFT tolerated (0.17); PolyPhen benign (0.031); catalogued as COSV54591095; called by muse, mutect2, varscan2
- ACSS3 | c.1594C>T p.P532S | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.824); catalogued as rs1247209581, COSV54084933; called by muse, mutect2, varscan2
- ACTL7B | c.128C>T p.P43L | Missense Mutation (SNP) | VAF 43/136 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.154); catalogued as COSV101012485; called by muse, mutect2, varscan2
- ADA2 | c.1360G>A p.D454N (on ENST00000262607; = p.D213N on NM_177405.3) | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52830873, COSV52833424; called by muse, mutect2, varscan2
- ADAD1 | c.253G>A p.E85K | Missense Mutation (SNP) | VAF 23/95 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.177); catalogued as rs867796878, COSV56641957; called by muse, mutect2, varscan2
- ADAM28 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 33/121 reads (27%) | SIFT tolerated (0.14); PolyPhen benign (0.054); catalogued as rs1272781925, COSV56104955; called by muse, mutect2, varscan2
- ADAM29 | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 15/71 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.794); catalogued as rs867060959, COSV63662440; called by muse, mutect2, varscan2
- ADAM32 | c.724G>A p.E242K | Missense Mutation (SNP) | VAF 28/96 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.059); catalogued as COSV65947132; called by muse, mutect2, varscan2
- ADAMTS20 | c.1124C>T p.S375L | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.089); catalogued as COSV67125970; called by muse, mutect2, varscan2
- ADAMTS20 | c.628G>A p.E210K | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67130027; called by muse, mutect2, varscan2
- ADCY10 | c.2780G>A p.R927Q | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.859); catalogued as COSV63240936; called by muse, mutect2, varscan2
- ADCY10 | c.2201C>T p.P734L | Missense Mutation (SNP) | VAF 87/156 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100896563; called by muse, mutect2, varscan2
- ADCY8 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV53903673; called by muse, mutect2, varscan2
- ADCYAP1R1 | c.121G>A p.A41T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.19); PolyPhen benign (0.306); catalogued as rs1280031818, COSV100416181; called by muse, mutect2, varscan2
- ADGRB3 | c.2481G>A p.T827= | Splice Region (SNP) | VAF 65/177 reads (37%) | catalogued as COSV99483594; called by muse, mutect2, varscan2
- ADGRB3 | c.2597C>T p.P866L | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.84); catalogued as COSV99483595; called by muse, mutect2, varscan2
- ADGRB3 | c.3497A>T p.Q1166L | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as COSV99483599; called by muse, mutect2, varscan2
- ADGRE1 | c.217G>A p.D73N | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.17); PolyPhen benign (0.111); catalogued as rs767902336, COSV51675820; called by muse, mutect2, varscan2
- ADGRE1 | c.1285C>T p.R429W | Missense Mutation (SNP) | VAF 44/115 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.642); catalogued as rs376031317, COSV51672479; called by muse, mutect2, varscan2
- ADGRG4 | c.5417C>T p.S1806F | Missense Mutation (SNP) | VAF 36/71 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.198); catalogued as rs746916419, COSV99794311; called by muse, mutect2, varscan2
- ADGRG5 | c.36C>A p.C12* | Nonsense Mutation (SNP) | VAF 11/42 reads (26%) | catalogued as rs1194560767, COSV100446334; called by muse, mutect2, varscan2
- ADGRV1 | c.14867G>A p.R4956K | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT tolerated (0.32); PolyPhen benign (0); catalogued as rs1457906021, COSV101315490; called by muse, mutect2, varscan2
- ADH1C | c.797C>T p.S266L | Missense Mutation (SNP) | VAF 78/263 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1005267020, COSV72463393; called by muse, mutect2
- ADIPOQ | c.216T>A p.G72= | Splice Region (SNP) | VAF 17/109 reads (16%) | catalogued as COSV100292081; called by muse, mutect2, varscan2
- ADIPOQ | c.217C>T p.L73F | Missense Mutation (SNP) | VAF 17/108 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.033); catalogued as COSV100292083; called by muse, mutect2, varscan2
- AFF3 | c.325G>A p.D109N | Missense Mutation (SNP) | VAF 34/109 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.435); catalogued as rs556588114, COSV100417689; called by muse, mutect2, varscan2
- AGXT2 | c.704C>T p.P235L | Missense Mutation (SNP) | VAF 7/22 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.055); catalogued as rs760186621, COSV99183702; called by muse, mutect2, varscan2
- AHCYL2 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 27/70 reads (39%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as rs200412891, COSV100272893; called by muse, mutect2, varscan2
- AK7 | c.248C>T p.S83F | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.302); catalogued as COSV99966979; called by muse, mutect2, varscan2
- AK9 | c.946C>T p.R316C | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as rs868260985, COSV53419508; called by muse, mutect2, varscan2
- AKAP6 | c.6236A>T p.N2079I | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT tolerated (0.2); PolyPhen benign (0.024); catalogued as COSV99798264; called by muse, mutect2, varscan2
- ALCAM | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT tolerated (0.05); PolyPhen benign (0.267); catalogued as COSV100064227; called by muse, mutect2, varscan2
- ALDH3B2 | c.805G>A p.E269K | Missense Mutation (SNP) | VAF 20/69 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.631); catalogued as rs745389018, COSV62428159; called by muse, mutect2, varscan2
- ALDH5A1 | c.842C>T p.S281F | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267600900, COSV62372745; called by muse, mutect2, varscan2
- ALMS1 | c.7343C>T p.P2448L | Missense Mutation (SNP) | VAF 15/90 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100041114; called by muse, mutect2, varscan2
- AMBP | c.481C>T p.L161F | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99468775; called by muse, mutect2, varscan2
- AMER3 | c.1243G>A p.D415N | Missense Mutation (SNP) | VAF 25/52 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs776197488, COSV100365953; called by muse, mutect2, varscan2
- AMPD3 | c.862C>T p.H288Y (on ENST00000396553 / NM_001025389.2; = p.H297Y on NM_000480.3) | Missense Mutation (SNP) | VAF 60/151 reads (40%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.468); catalogued as COSV101158080; called by muse, mutect2, varscan2
- ANAPC7 | c.1673C>T p.P558L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.65); PolyPhen benign (0.11); catalogued as COSV101482838; called by muse, mutect2, varscan2
- ANK3 | c.5724G>A p.M1908I | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as COSV55050659; called by muse, mutect2, varscan2
- ANKRD11 | c.6055C>T p.P2019S | Missense Mutation (SNP) | VAF 9/22 reads (41%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.311); catalogued as rs1165374364, COSV99968253; called by muse, mutect2, varscan2
- ANKRD30A | c.3166G>A p.E1056K (on ENST00000611781; = p.E1000K on NM_052997.2) | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT tolerated (0.24); PolyPhen benign (0.125); catalogued as rs746442980, COSV64610968; called by muse, mutect2, varscan2
- ANKS3 | c.700C>T p.R234W | Missense Mutation (SNP) | VAF 16/46 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs139960829; called by muse, mutect2, varscan2
- APBB2 | c.329C>T p.A110V | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.997); catalogued as COSV99922420; called by muse, mutect2, varscan2
- APOB | c.8587G>A p.E2863K | Missense Mutation (SNP) | VAF 113/265 reads (43%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.786); catalogued as COSV51941363, COSV51954769; called by muse, mutect2, varscan2
- ARAP2 | c.1724C>T p.S575L | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as COSV100394105; called by muse, mutect2, varscan2
- ARHGAP21 | c.1648C>T p.H550Y | Missense Mutation (SNP) | VAF 36/135 reads (27%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.849); catalogued as COSV57604453, COSV57604766; called by muse, mutect2, varscan2
- ARHGAP44 | c.1174C>T p.Q392* | Nonsense Mutation (SNP) | VAF 12/29 reads (41%) | catalogued as COSV99310055; called by muse, mutect2, varscan2
- ARHGEF2 | c.1948C>T p.R650C (on ENST00000361247 / NM_001162383.2; = p.R622C on NM_004723.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/72 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs768385602, COSV58111891; called by muse, mutect2, varscan2
- ARHGEF5 | c.515C>T p.T172I | Missense Mutation (SNP) | VAF 24/224 reads (11%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs766454819, COSV99282541; called by muse, mutect2, varscan2
- ARID2 | c.928C>T p.R310C | Missense Mutation (SNP) | VAF 46/162 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV57600152; called by muse, mutect2, varscan2
- ARID2 | c.3151C>T p.Q1051* | Nonsense Mutation (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100535374; called by muse, mutect2, varscan2
- ARID5A | c.1187C>T p.P396L | Missense Mutation (SNP) | VAF 8/33 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100673527, COSV100673636; called by muse, mutect2, varscan2
- ARL13B | c.665G>A p.R222Q (on ENST00000394222 / NM_001174150.2; = p.R115Q on NM_144996.4) | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as rs1478163991, COSV100115133; called by muse, mutect2, varscan2
- ARL16 | c.5G>A p.R2K | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV100230203, COSV61267927; called by muse, mutect2, varscan2
- ARPP21 | c.510G>A p.M170I | Missense Mutation (SNP) | VAF 10/70 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.205); catalogued as rs1006720917, COSV99490923; called by muse, mutect2
- ARSG | c.50G>A p.G17E | Missense Mutation (SNP) | VAF 43/157 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101477869, COSV71593268; called by muse, mutect2, varscan2
- ARSH | c.202C>T p.P68S | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.895); catalogued as COSV66963611; called by muse, mutect2, varscan2
- ASAH2 | c.619G>A p.V207M | Missense Mutation (SNP) | VAF 51/208 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.411); catalogued as rs1002426861; called by muse, mutect2, varscan2
- ASB10 | c.247C>T p.P83S | Missense Mutation (SNP) | VAF 23/37 reads (62%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.985); catalogued as COSV99318148; called by muse, mutect2, varscan2
- ASB10 | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 22/34 reads (65%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV99318151; called by muse, mutect2, varscan2
- ASL | c.1264G>A p.G422S | Missense Mutation (SNP) | VAF 37/118 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0); catalogued as COSV100508813; called by muse, mutect2, varscan2
- ASNS | c.142C>T p.H48Y | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99445854, COSV99445917; called by muse, mutect2, varscan2
- ASTN2 | c.1775G>A p.G592D (on ENST00000313400 / NM_001365069.1; = p.G541D on NM_014010.5) | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV100524696; called by muse, mutect2, varscan2
- ASTN2 | c.1423+1G>A p.X475_splice (on ENST00000313400 / NM_001365069.1; = p.X424_splice on NM_014010.5) | Splice Site (SNP) | VAF 12/52 reads (23%) | catalogued as COSV100524699; called by muse, mutect2, varscan2
- ASXL1 | c.3865C>T p.R1289W | Missense Mutation (SNP) | VAF 20/86 reads (23%) | SIFT tolerated (0.08); PolyPhen benign (0.021); catalogued as rs201302084, COSV60120509; called by muse, mutect2, varscan2
- ASXL3 | c.1515G>A p.M505I | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.914); catalogued as rs547738110, COSV99323390; called by muse, mutect2
- ASXL3 | c.4108C>T p.P1370S | Missense Mutation (SNP) | VAF 38/128 reads (30%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.007); catalogued as rs1349869581, COSV52458378; called by muse, mutect2, varscan2
- ASZ1 | c.989T>C p.L330P | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.815); catalogued as COSV99497749; called by muse, mutect2, varscan2
- ASZ1 | c.988C>T p.L330F | Missense Mutation (SNP) | VAF 19/112 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.015); catalogued as COSV99497750; called by muse, mutect2, varscan2
- ATG2B | c.3922C>T p.R1308C | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.963); catalogued as rs772425977, COSV55890367; called by muse, mutect2, varscan2
- ATM | c.6166C>T p.P2056S | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.88); PolyPhen benign (0); catalogued as COSV53753855; called by muse, mutect2, varscan2
- ATP10D | c.2239C>T p.R747W | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs756861814, COSV56708945; called by muse, mutect2, varscan2
- ATP11C | c.1064A>G p.N355S | Missense Mutation (SNP) | VAF 39/58 reads (67%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100557371; called by muse, mutect2, varscan2
- ATP13A2 | c.3296C>T p.P1099L | Missense Mutation (SNP) | VAF 14/26 reads (54%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.898); catalogued as rs1488939495, COSV100453903; called by muse, mutect2, varscan2
- ATP13A5 | c.2552G>A p.G851E | Missense Mutation (SNP) | VAF 23/46 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60868908; called by muse, mutect2, varscan2
- ATP13A5 | c.1759-1G>A p.X587_splice | Splice Site (SNP) | VAF 25/57 reads (44%) | catalogued as COSV100664730; called by muse, mutect2, varscan2
- ATP2C1 | c.2618T>C p.L873P | Missense Mutation (SNP) | VAF 16/96 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1481680820, COSV100146252; called by muse, mutect2, varscan2
- ATP6V0D2 | c.680C>T p.S227F | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99571299; called by muse, mutect2, varscan2
- ATP7A | c.989C>T p.S330F | Missense Mutation (SNP) | VAF 101/166 reads (61%) | SIFT deleterious (0.05); PolyPhen benign (0.038); catalogued as COSV58450793; called by muse, mutect2, varscan2
- ATP7B | c.1045C>T p.P349S | Missense Mutation (SNP) | VAF 36/111 reads (32%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as rs1226407854, COSV99666016; called by muse, mutect2, varscan2
- ATP8B4 | c.2767G>A p.G923R | Missense Mutation (SNP) | VAF 36/74 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99463663; called by muse, mutect2, varscan2
- AUTS2 | c.2303C>T p.S768F | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.83); catalogued as COSV61431523; called by muse, mutect2, varscan2
- B3GAT2 | c.727G>A p.D243N | Missense Mutation (SNP) | VAF 16/40 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1445262803, COSV57771511; called by muse, mutect2, varscan2
- B4GALNT2 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.014); catalogued as rs780338935, COSV55928398; called by muse, mutect2, varscan2
- BCAM | c.565G>A p.G189R | Missense Mutation (SNP) | VAF 23/70 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.241); catalogued as rs749304808, COSV54300397; called by muse, mutect2, varscan2
- BCAM | c.1562C>T p.S521F | Missense Mutation (SNP) | VAF 24/95 reads (25%) | SIFT tolerated (0.34); PolyPhen probably damaging (0.966); catalogued as COSV54305647; called by muse, mutect2, varscan2
- BCAS1 | c.1532A>G p.K511R | Missense Mutation (SNP) | VAF 29/127 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); catalogued as COSV101006015; called by muse, mutect2, varscan2
- BCLAF1 | c.674C>T p.S225L | Missense Mutation (SNP) | VAF 13/153 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs867887734, COSV62141504; called by muse, mutect2
- BCLAF1 | c.329C>T p.S110L | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.158); catalogued as rs1365362293, COSV62143097; called by mutect2, varscan2
- BCO1 | c.406T>C p.Y136H | Missense Mutation (SNP) | VAF 40/115 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.272); catalogued as COSV99257397; called by muse, mutect2, varscan2
- BEND2 | c.1549G>A p.E517K | Missense Mutation (SNP) | VAF 116/188 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.326); catalogued as rs756416335, COSV66217700; called by muse, mutect2, varscan2
- BEST3 | c.1781G>A p.G594E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV58304093, COSV58305929; called by muse, mutect2, varscan2
- BEST3 | c.20G>A p.S7N | Missense Mutation (SNP) | VAF 40/121 reads (33%) | SIFT tolerated (0.22); PolyPhen benign (0.241); catalogued as rs1326219222, COSV99876066; called by muse, mutect2, varscan2
- BMP5 | c.427G>A p.A143T | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.119); catalogued as COSV100895754; called by muse, mutect2, varscan2
- BMP6 | c.857G>A p.R286K | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.07); PolyPhen benign (0.326); catalogued as COSV99306319; called by muse, mutect2
- BOD1L1 | c.6835C>T p.P2279S | Missense Mutation (SNP) | VAF 4/27 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.254); catalogued as rs920210808, COSV99238367; called by muse, mutect2, varscan2
- BRD8 | c.2816G>A p.R939K | Missense Mutation (SNP) | VAF 65/202 reads (32%) | SIFT tolerated, low confidence (0.35); PolyPhen benign (0); catalogued as rs758983450, COSV99136581; called by muse, mutect2, varscan2
- BRD9 | c.1396C>T p.P466S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT tolerated (0.27); PolyPhen benign (0.082); catalogued as COSV60246344; called by muse, mutect2, varscan2
- BROX | c.164A>G p.E55G | Missense Mutation (SNP) | VAF 96/173 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.021); catalogued as rs928646385, COSV100572065; called by muse, mutect2, varscan2
- BRPF1 | c.233C>T p.P78L | Missense Mutation (SNP) | VAF 76/171 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.287); catalogued as COSV57404444; called by muse, mutect2, varscan2
- BRPF3 | c.52C>T p.P18S | Missense Mutation (SNP) | VAF 16/68 reads (24%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as COSV60208319; called by muse, mutect2, varscan2
- BSN | c.286C>T p.P96S | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.01); catalogued as COSV56516519; called by muse, mutect2, varscan2
- BTBD11 | c.2566G>A p.E856K (on ENST00000280758 / NM_001018072.2; = p.E393K on NM_001017523.2) | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.473); catalogued as COSV99774720; called by muse, mutect2, varscan2
- BTBD11 | c.2743C>T p.H915Y (on ENST00000280758 / NM_001018072.2; = p.H452Y on NM_001017523.2) | Missense Mutation (SNP) | VAF 23/86 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.715); catalogued as COSV99774723; called by muse, mutect2, varscan2
- BTN3A2 | c.674C>T p.S225F | Missense Mutation (SNP) | VAF 49/199 reads (25%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.753); catalogued as COSV100709553; called by muse, mutect2, varscan2
- BVES | c.765del p.D256Tfs*9 | Frame Shift Del (DEL) | VAF 26/130 reads (20%) | catalogued as rs1303345960; called by pindel, varscan2
- C10orf120 | c.787C>T p.R263C | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as rs748398816, COSV100271529; called by muse, mutect2, varscan2
- C10orf71 | c.1960C>T p.P654S | Missense Mutation (SNP) | VAF 5/21 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs762084079, COSV100109700; called by mutect2, varscan2
- C11orf53 | c.297del p.A100Qfs*26 | Frame Shift Del (DEL) | VAF 42/116 reads (36%) | catalogued as COSV54720892; called by mutect2, pindel*, varscan2
- C3 | c.3478G>A p.E1160K | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.04); catalogued as CM153563, COSV55580252; called by muse, mutect2, varscan2
- C3AR1 | c.1294C>T p.P432S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs773756132, COSV99368093, COSV99368203; called by muse, mutect2, varscan2
- C3AR1 | c.1130G>A p.R377Q | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT tolerated (0.28); PolyPhen benign (0.146); catalogued as rs751723531, COSV99368035; called by muse, mutect2, varscan2
- C3orf56 | c.50C>T p.A17V | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated, low confidence (0.12); PolyPhen probably damaging (0.97); catalogued as rs1360027412, COSV101228924; called by muse, mutect2
- C5 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 22/97 reads (23%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.992); catalogued as rs1219211409, COSV99797110; called by muse, mutect2, varscan2
- C6 | c.1674T>A p.D558E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV99666493; called by muse, mutect2, varscan2
- C6orf15 | c.709G>A p.G237R | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99456631; called by muse, mutect2, varscan2
- C9 | c.931C>T p.R311C | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs371134723; called by muse, mutect2, varscan2
- CACNA1E | c.6254G>A p.R2085Q (on ENST00000367573 / NM_001205293.3; = p.R2042Q on NM_000721.4) | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.658); catalogued as COSV62403523; called by muse, mutect2, varscan2
- CACNA1G | c.6902G>C p.R2301P | Missense Mutation (SNP) | VAF 10/20 reads (50%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.693); catalogued as rs757138454, COSV100661139, COSV100661484; called by muse, varscan2
- CACNA1H | c.1069G>A p.G357S | Missense Mutation (SNP) | VAF 18/51 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772864652, COSV61987906; called by muse, mutect2, varscan2
- CACNA2D3 | c.1637G>A p.G546E | Missense Mutation (SNP) | VAF 11/72 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55513847; called by muse, mutect2, varscan2
- CACNA2D4 | c.2191G>A p.V731M | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.94); catalogued as COSV54948398; called by muse, mutect2
- CACNB2 | c.1912G>A p.D638N (on ENST00000324631 / NM_201596.3; = p.D583N on NM_000724.4) | Missense Mutation (SNP) | VAF 22/84 reads (26%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.285); catalogued as rs142735478, COSV56651738; called by muse, mutect2, varscan2
- CADPS | c.982C>T p.P328S | Missense Mutation (SNP) | VAF 52/114 reads (46%) | SIFT deleterious (0); PolyPhen benign (0.328); catalogued as rs774869379, COSV51882766; called by muse, mutect2, varscan2
- CAND1 | c.3169A>T p.K1057* | Nonsense Mutation (SNP) | VAF 47/139 reads (34%) | catalogued as COSV101607296; called by muse, mutect2, varscan2
- CAP2 | c.403G>A p.A135T | Missense Mutation (SNP) | VAF 29/99 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.86); catalogued as rs1285194437, COSV100012066; called by muse, mutect2, varscan2
- CARD6 | c.1084G>A p.V362M | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT tolerated (0.47); PolyPhen benign (0.022); catalogued as COSV99620159; called by muse, mutect2, varscan2
- CASD1 | c.752T>C p.V251A | Missense Mutation (SNP) | VAF 88/188 reads (47%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.992); catalogued as COSV99802265; called by muse, mutect2, varscan2
- CCBE1 | c.1123C>T p.P375S | Missense Mutation (SNP) | VAF 53/149 reads (36%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV67950008; called by muse, mutect2, varscan2
- CCDC102A | c.785C>T p.S262F | Missense Mutation (SNP) | VAF 5/12 reads (42%) | SIFT tolerated (0.85); PolyPhen possibly damaging (0.884); catalogued as COSV99264787; called by muse, mutect2, varscan2
- CCDC102B | c.1363G>A p.E455K | Missense Mutation (SNP) | VAF 18/49 reads (37%) | SIFT deleterious (0.04); PolyPhen benign (0.181); catalogued as rs1377824417, COSV60148756; called by muse, mutect2, varscan2
- CCDC144A | c.373G>A p.E125K | Missense Mutation (SNP) | VAF 12/34 reads (35%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.001); catalogued as COSV100501938; called by mutect2, varscan2
- CCDC144A | c.3709G>A p.E1237K | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.14); PolyPhen benign (0.046); catalogued as rs750327075, COSV100138327; called by muse, varscan2
- CCDC146 | c.1085G>A p.R362Q | Missense Mutation (SNP) | VAF 26/120 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.471); catalogued as rs552375827, COSV53544047, COSV99035595; called by muse, mutect2, varscan2
- CCDC181 | c.1079G>A p.R360Q | Missense Mutation (SNP) | VAF 47/86 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.159); catalogued as rs530288123, COSV63155897; called by muse, mutect2, varscan2
- CCDC3 | c.375-1G>A p.X125_splice | Splice Site (SNP) | VAF 21/61 reads (34%) | catalogued as rs1029998622, COSV101121614; called by muse, mutect2, varscan2
- CCDC69 | c.332C>T p.S111L | Missense Mutation (SNP) | VAF 17/38 reads (45%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.73); catalogued as COSV100815078; called by muse, mutect2, varscan2
- CCDC7 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.113); catalogued as COSV99511302; called by muse, mutect2, varscan2
- CCDC74B | c.800G>A p.R267Q | Missense Mutation (SNP) | VAF 46/169 reads (27%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.992); catalogued as rs140048183, COSV60103436; called by muse, mutect2, varscan2
- CCKAR | c.978G>A p.W326* | Nonsense Mutation (SNP) | VAF 21/100 reads (21%) | catalogued as rs772585152, COSV99810091; called by muse, mutect2, varscan2
- CD226 | c.574C>T p.P192S | Missense Mutation (SNP) | VAF 27/89 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.01); catalogued as COSV99710748; called by muse, mutect2, varscan2
- CD86 | c.868G>A p.E290K (on ENST00000330540 / NM_175862.5; = p.E284K on NM_006889.4) | Missense Mutation (SNP) | VAF 20/43 reads (47%) | SIFT tolerated (0.77); PolyPhen benign (0.001); catalogued as COSV100053831; called by muse, mutect2, varscan2
- CD93 | c.145G>A p.A49T | Missense Mutation (SNP) | VAF 3/13 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1454138921, COSV99848889; called by muse, mutect2
- CDC42BPB | c.3301C>T p.H1101Y | Missense Mutation (SNP) | VAF 46/161 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100775175; called by muse, mutect2, varscan2
- CDH10 | c.1495G>A p.E499K | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100050394, COSV52573394; called by muse, mutect2, varscan2
- CDH13 | c.820G>A p.D274N | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1480218693, COSV99222359; called by muse, varscan2
- CDH17 | c.1606C>T p.P536S | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50330515; called by muse, mutect2, varscan2
- CDH23 | c.6664C>T p.R2222C | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.014); catalogued as rs761082272, COSV56498799; ClinVar: uncertain significance; called by muse, mutect2
- CDH26 | c.2459C>T p.P820L (on ENST00000348616 / NM_177980.4; = p.P153L on NM_021810.6) | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs773831785, COSV99721775, COSV99722858; called by muse, mutect2, varscan2
- CDH6 | c.379C>T p.R127* | Nonsense Mutation (SNP) | VAF 58/169 reads (34%) | catalogued as rs1478053605, COSV54075499; called by muse, mutect2, varscan2
- CDH6 | c.1000C>T p.L334F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.17); catalogued as rs781442002, COSV54067394; called by muse, mutect2, varscan2
- CDH6 | c.1246C>T p.P416S | Missense Mutation (SNP) | VAF 7/41 reads (17%) | SIFT tolerated (0.17); PolyPhen benign (0.098); catalogued as COSV99418043; called by muse, mutect2, varscan2
- CDK11B | c.140C>T p.S47F | Missense Mutation (SNP) | VAF 18/35 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV100477249; called by muse, mutect2, varscan2
- CDK5RAP1 | c.1097C>T p.P366L (on ENST00000357886 / NM_001365728.1; = p.P352L on NM_016082.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100211865; called by muse, mutect2, varscan2
- CDKN2C | c.358G>A p.E120K | Missense Mutation (SNP) | VAF 42/54 reads (78%) | SIFT tolerated (0.52); PolyPhen benign (0.007); catalogued as COSV99395697; called by muse, mutect2, varscan2
- CDSN | c.1142G>A p.G381E | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.548); catalogued as rs1472190541, COSV99456632; called by muse, mutect2, varscan2
- CEACAM3 | c.487G>A p.G163R | Missense Mutation (SNP) | VAF 36/128 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.01); catalogued as rs562109340, COSV55761154; called by muse, mutect2, varscan2
- CEMIP2 | c.4103T>A p.V1368D | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.034); catalogued as COSV100987226; called by muse, mutect2, varscan2
- CEP128 | c.3145C>T p.R1049C | Missense Mutation (SNP) | VAF 26/89 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs373014765; called by muse, mutect2, varscan2
- CEP192 | c.4556C>T p.P1519L | Missense Mutation (SNP) | VAF 26/95 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100380568; called by muse, mutect2, varscan2
- CES3 | c.749G>A p.R250K | Missense Mutation (SNP) | VAF 22/91 reads (24%) | SIFT tolerated (0.71); PolyPhen probably damaging (0.986); catalogued as rs762013442, COSV100309794; called by muse, mutect2, varscan2
- CES5A | c.1060G>A p.E354K | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.65); PolyPhen benign (0.018); catalogued as rs1390010276, COSV51870031; called by muse, mutect2, varscan2
- CES5A | c.1059G>A p.K353= | Splice Region (SNP) | VAF 23/80 reads (29%) | catalogued as COSV51868530; called by muse, mutect2, varscan2
- CFAP298-TCP10L | c.1102C>T p.R368C | Missense Mutation (SNP) | VAF 24/90 reads (27%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.041); catalogued as rs145109364; called by muse, mutect2, varscan2
- CFAP65 | c.3251C>T p.S1084F | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as rs750909827, COSV100444581; called by muse, mutect2, varscan2
- CFHR2 | c.700G>A p.G234S | Missense Mutation (SNP) | VAF 78/144 reads (54%) | SIFT deleterious (0.01); PolyPhen benign (0.211); catalogued as rs1275927206, COSV100804233; called by muse, varscan2
- CHGB | c.1088G>A p.R363K | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT tolerated (0.37); PolyPhen benign (0.089); catalogued as COSV100972907; called by muse, mutect2, varscan2
- CHMP4C | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 12/33 reads (36%) | SIFT tolerated (0.72); PolyPhen benign (0.006); catalogued as COSV99794039; called by muse, mutect2, varscan2
- CHRNG | c.576G>A p.W192* | Nonsense Mutation (SNP) | VAF 12/55 reads (22%) | catalogued as COSV101263892; called by muse, mutect2, varscan2
- CLASP2 | c.1023T>G p.D341E | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.034); catalogued as COSV100222506; called by muse, mutect2, varscan2
- CLK2 | c.1227A>G p.R409= (on ENST00000368361 / NM_001294339.2; = p.R408= on NM_003993.4) | Splice Region (SNP) | VAF 82/149 reads (55%) | catalogued as COSV100226585; called by muse, mutect2, varscan2
- CLP1 | c.98T>C p.V33A | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.04); catalogued as COSV100239717; called by muse, mutect2, varscan2
- CLRN3 | c.98G>A p.W33* | Nonsense Mutation (SNP) | VAF 39/122 reads (32%) | catalogued as COSV64099208; called by muse, mutect2, varscan2
- CLSPN | c.1105A>C p.T369P | Missense Mutation (SNP) | VAF 55/103 reads (53%) | SIFT tolerated (0.07); PolyPhen benign (0.154); catalogued as COSV99230277; called by muse, mutect2, varscan2
- CLSTN3 | c.2140G>A p.G714R | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99866515; called by muse, mutect2, varscan2
- CMSS1 | c.275C>T p.P92L | Missense Mutation (SNP) | VAF 48/126 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101375468; called by muse, mutect2, varscan2
- CMTR2 | c.1526C>T p.P509L | Missense Mutation (SNP) | VAF 14/64 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.255); catalogued as COSV100578973; called by muse, mutect2, varscan2
- CNBD2 | c.1313G>A p.R438Q (on ENST00000373973 / NM_001365709.1; = p.R434Q on NM_080834.4) | Missense Mutation (SNP) | VAF 45/101 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs773539864, COSV100839046; called by muse, mutect2, varscan2
- CNGA1 | c.1874G>A p.R625Q | Missense Mutation (SNP) | VAF 42/123 reads (34%) | SIFT tolerated (0.22); PolyPhen benign (0.011); catalogued as rs373782782; called by muse, mutect2, varscan2
- CNGB3 | c.2212G>A p.E738K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.48); PolyPhen benign (0.351); catalogued as rs1466372683, COSV100181178; called by muse, mutect2, varscan2
- CNPPD1 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 31/77 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758767449, COSV99811360; called by muse, mutect2, varscan2
- CNR1 | c.238G>A p.E80K | Missense Mutation (SNP) | VAF 27/64 reads (42%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.025); catalogued as COSV62987339, COSV62987433; called by muse, mutect2, varscan2
- CNTNAP3 | c.3724A>G p.R1242G | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1027608573, COSV99904094; called by muse, mutect2
- CNTNAP4 | c.1237C>T p.Q413* | Nonsense Mutation (SNP) | VAF 26/89 reads (29%) | catalogued as COSV100269367; called by muse, mutect2, varscan2
- COL14A1 | c.847C>T p.R283C | Missense Mutation (SNP) | VAF 32/109 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs1270185548, COSV99918006; called by muse, mutect2, varscan2
- COL14A1 | c.3919G>A p.E1307K | Missense Mutation (SNP) | VAF 34/101 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52847444; called by muse, mutect2, varscan2
- COL14A1 | c.4675G>A p.D1559N | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious (0.02); PolyPhen benign (0.18); catalogued as rs777777699, COSV52866968; called by muse, mutect2, varscan2
- COL17A1 | c.556C>T p.P186S | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100793040; called by muse, mutect2, varscan2
- COL1A2 | c.2335G>A p.D779N | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.637); catalogued as rs758781213, COSV51964557; called by muse, mutect2, varscan2
- COL27A1 | c.2522G>A p.G841E | Missense Mutation (SNP) | VAF 52/216 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100620721; called by muse, mutect2, varscan2
- COL2A1 | c.2625G>A p.Q875= | Splice Region (SNP) | VAF 8/16 reads (50%) | catalogued as rs1366355382, COSV100475460; called by muse, mutect2, varscan2
- COL3A1 | c.4151G>A p.G1384E | Missense Mutation (SNP) | VAF 23/93 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767716621, COSV100482444; called by muse, mutect2, varscan2
- COL4A4 | c.1898G>A p.G633E | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61629245; called by mutect2, varscan2
- COL5A1 | c.2423G>A p.G808D | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65676030; called by muse, mutect2, varscan2
- COL5A3 | c.2719C>T p.Q907* | Nonsense Mutation (SNP) | VAF 29/104 reads (28%) | catalogued as COSV99318218; called by muse, mutect2, varscan2
- COL5A3 | c.1834C>T p.P612S | Missense Mutation (SNP) | VAF 19/44 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.005); catalogued as COSV99318219; called by muse, mutect2, varscan2
- COL6A5 | c.7537C>T p.P2513S (on ENST00000312481; = p.P2509S on NM_153264.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/47 reads (32%) | SIFT deleterious (0.04); PolyPhen benign (0.021); catalogued as COSV99591908; called by muse, mutect2, varscan2
- COL7A1 | c.8110G>A p.G2704R | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as COSV56477405; called by muse, mutect2, varscan2
- CORO7 | c.1741G>A p.E581K | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as COSV99227175; called by muse, mutect2, varscan2
- CP | c.2228G>A p.W743* | Nonsense Mutation (SNP) | VAF 59/277 reads (21%) | catalogued as COSV99223714; called by muse, mutect2, varscan2
- CPD | c.1519C>T p.P507S | Missense Mutation (SNP) | VAF 41/126 reads (33%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as rs1018733857, COSV99852455; called by muse, mutect2, varscan2
- CPXM1 | c.419T>C p.L140P | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101013678; called by muse, mutect2, varscan2
- CPXM2 | c.919G>A p.E307K | Missense Mutation (SNP) | VAF 28/102 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs751380071, COSV53872919; called by muse, mutect2, varscan2
- CR1 | c.4465C>T p.R1489* | Nonsense Mutation (SNP) | VAF 25/165 reads (15%) | catalogued as rs778591697, COSV65456307; called by muse, mutect2, varscan2
- CRB1 | c.535C>T p.Q179* | Nonsense Mutation (SNP) | VAF 19/71 reads (27%) | catalogued as COSV100958337; called by muse, mutect2, varscan2
- CSMD1 | c.9740G>A p.G3247D (on ENST00000520002; = p.G3246D on NM_033225.6) | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748444661, COSV100143714; called by muse, varscan2
- CSMD1 | c.9551C>T p.S3184F (on ENST00000520002; = p.S3183F on NM_033225.6) | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.207); catalogued as COSV59285116; called by muse, mutect2, varscan2
- CSMD1 | c.8227G>A p.G2743R (on ENST00000520002; = p.G2742R on NM_033225.6) | Missense Mutation (SNP) | VAF 28/87 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59359578, COSV59372481; called by muse, mutect2, varscan2
- CSMD1 | c.4640C>T p.S1547F (on ENST00000520002; = p.S1546F on NM_033225.6) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV100143726; called by mutect2, varscan2
- CSMD1 | c.3563C>T p.S1188F (on ENST00000520002; = p.S1187F on NM_033225.6) | Missense Mutation (SNP) | VAF 7/32 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV100144590, COSV59399107; called by muse, mutect2, varscan2
- CSMD2 | c.2482C>T p.P828S | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1256151793, COSV53879518, COSV99596900; called by muse, mutect2, varscan2
- CSMD3 | c.4568C>T p.S1523F (on ENST00000297405 / NM_001363185.1; = p.S1419F on NM_052900.3) | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.943); catalogued as COSV52103216, COSV52110256; called by muse, mutect2
- CSMD3 | c.376C>T p.P126S | Missense Mutation (SNP) | VAF 30/88 reads (34%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.996); catalogued as rs758502651, COSV99824610; called by muse, mutect2, varscan2
- CSPG5 | c.1075T>G p.C359G | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99273613, COSV99274206; called by muse, mutect2, varscan2
- CTAGE1 | c.317G>A p.R106K | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.44); PolyPhen benign (0.012); catalogued as COSV101194431; called by muse, mutect2, varscan2
- CTAGE15 | c.1345C>T p.H449Y | Missense Mutation (SNP) | VAF 9/45 reads (20%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.499); catalogued as rs928470188, COSV101372114; called by mutect2, varscan2
- CTAGE6 | c.1226G>A p.R409Q | Missense Mutation (SNP) | VAF 67/232 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as rs779951636, COSV69916572, COSV69917874; called by muse, mutect2, varscan2
- CTBP2 | c.101C>T p.P34L | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs796256730, COSV58334223; called by muse, mutect2, varscan2
- CTTN | c.341A>C p.Q114P | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100097129; called by muse, mutect2, varscan2
- CUL9 | c.2816C>T p.P939L | Missense Mutation (SNP) | VAF 121/240 reads (50%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.791); catalogued as COSV99334750; called by muse, mutect2, varscan2
- CUZD1 | c.1040C>T p.S347F | Missense Mutation (SNP) | VAF 25/86 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as COSV100158587; called by muse, mutect2, varscan2
- CXorf66 | c.773C>T p.S258F | Missense Mutation (SNP) | VAF 45/84 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as rs1230564375, COSV100983822; called by muse, mutect2, varscan2
- CYP27B1 | c.533G>A p.G178E | Missense Mutation (SNP) | VAF 3/14 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.038); catalogued as COSV99141497; called by muse, mutect2
- CYP2A6 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.34); catalogued as COSV56535934, COSV99991723; called by muse, mutect2, varscan2
- CYP2C18 | c.1138C>T p.L380F | Missense Mutation (SNP) | VAF 22/72 reads (31%) | SIFT tolerated (0.54); PolyPhen benign (0.003); catalogued as rs1564648078, COSV99608244; called by muse, mutect2, varscan2
- CYP2C9 | c.853G>A p.E285K | Missense Mutation (SNP) | VAF 46/159 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.105); catalogued as COSV99582171; called by muse, mutect2, varscan2
- CYP4B1 | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 26/55 reads (47%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.58); catalogued as rs367647904; called by muse, mutect2, varscan2
- CYP7B1 | c.123G>A p.R41= | Splice Region (SNP) | VAF 40/98 reads (41%) | catalogued as COSV59585243, COSV59586168; called by muse, mutect2, varscan2
- CYSLTR1 | c.382C>T p.P128S | Missense Mutation (SNP) | VAF 22/36 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100964704; called by muse, mutect2, varscan2
- DAO | c.733G>A p.G245R | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV99948429; called by muse, mutect2, varscan2
- DAOA | c.152G>A p.G51E | Missense Mutation (SNP) | VAF 15/40 reads (38%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.751); catalogued as COSV100298683; called by muse, mutect2, varscan2
- DAW1 | c.839C>T p.S280F | Missense Mutation (SNP) | VAF 21/99 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1490532870, COSV59369066; called by muse, mutect2, varscan2
- DCC | c.3393G>A p.K1131= | Splice Region (SNP) | VAF 16/43 reads (37%) | catalogued as COSV71427284; called by muse, mutect2, varscan2
- DCDC2 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 125/290 reads (43%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.001); catalogued as rs781230955, COSV65828654; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DCN | c.394G>A p.E132K | Missense Mutation (SNP) | VAF 61/180 reads (34%) | SIFT tolerated (0.42); PolyPhen benign (0.039); catalogued as rs754450177, COSV99271789; called by muse, mutect2, varscan2
- DDB2 | c.1235-1G>A p.X412_splice | Splice Site (SNP) | VAF 20/67 reads (30%) | catalogued as COSV99921434; called by muse, mutect2, varscan2
- DDI1 | c.509C>T p.A170V | Missense Mutation (SNP) | VAF 15/79 reads (19%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs1207859620, COSV100157797, COSV56381286; called by muse, mutect2, varscan2
- DDX3X | c.866C>T p.S289L (on ENST00000399959; = p.S290L on NM_001356.5) | Missense Mutation (SNP) | VAF 55/96 reads (57%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.77); catalogued as COSV67864313; called by muse, mutect2, varscan2
- DDX43 | c.651G>A p.R217= | Splice Region (SNP) | VAF 9/40 reads (23%) | catalogued as COSV100946220; called by muse, mutect2, varscan2
- DDX43 | c.927C>T p.S309= | Splice Region (SNP) | VAF 51/167 reads (31%) | catalogued as rs1202486385, COSV100946221; called by muse, mutect2, varscan2
- DEPP1 | c.394C>T p.L132F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0.346); catalogued as rs373182070; called by muse, mutect2, varscan2
- DGKB | c.1459C>T p.P487S | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.019); catalogued as rs1266187114, COSV51796132; called by muse, varscan2
- DGKB | c.1450C>T p.R484C | Missense Mutation (SNP) | VAF 18/38 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs369588680, COSV51769175; called by muse, varscan2
- DGKI | c.2150C>T p.P717L | Missense Mutation (SNP) | VAF 58/128 reads (45%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.621); catalogued as rs1200885974, COSV99932432; called by muse, mutect2, varscan2
- DHRS7C | c.785T>A p.V262E (on ENST00000330255 / NM_001220493.2; = p.V261E on NM_001105571.3) | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100364524; called by muse, mutect2
- DHRS9 | c.148G>A p.D50N | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as COSV59139195; called by muse, mutect2, varscan2
- DISP3 | c.3740C>T p.S1247F | Missense Mutation (SNP) | VAF 43/64 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs553635142, COSV99607333; called by muse, mutect2, varscan2
- DLG1 | c.2621G>A p.G874E (on ENST00000419354 / NM_001290983.1; = p.G896E on NM_004087.2) | Missense Mutation (SNP) | VAF 39/105 reads (37%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.893); catalogued as COSV100014589, COSV100015333; called by muse, mutect2, varscan2
- DLGAP2 | c.1057G>A p.A353T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.996); catalogued as COSV101421017, COSV70093709; called by muse, mutect2, varscan2
- DMBT1 | c.5366C>T p.S1789F (on ENST00000338354 / NM_001377530.1; = p.S1032F on NM_004406.3) | Missense Mutation (SNP) | VAF 106/366 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV57546599; called by muse, mutect2, varscan2
- DMBT1 | c.6322G>A p.E2108K (on ENST00000338354 / NM_001377530.1; = p.E1351K on NM_004406.3) | Missense Mutation (SNP) | VAF 50/156 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57546621; called by muse, mutect2, varscan2
- DNAH11 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV100177047; called by muse, mutect2, varscan2
- DNAH11 | c.10954G>A p.D3652N | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT tolerated (0.69); PolyPhen possibly damaging (0.723); catalogued as rs1409530873, COSV60939970, COSV60959242; called by muse, mutect2, varscan2
- DNAH17 | c.8671G>A p.E2891K | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.576); catalogued as rs777630121, COSV101101425; called by muse, mutect2, varscan2
- DNAH17 | c.8384G>A p.G2795E | Missense Mutation (SNP) | VAF 22/105 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs764265058, COSV67760163; called by muse, mutect2, varscan2
- DNAH2 | c.6646C>T p.P2216S | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1479864155, COSV66719250; called by muse, mutect2, varscan2
- DNAH5 | c.11047G>A p.E3683K | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs868795420, COSV54229306; called by muse, mutect2, varscan2
- DNAH5 | c.9706G>A p.D3236N | Missense Mutation (SNP) | VAF 58/190 reads (31%) | SIFT tolerated (0.31); PolyPhen benign (0.005); catalogued as rs374206128, COSV99451113; called by muse, mutect2, varscan2
- DNAH5 | c.9547C>T p.Q3183* | Nonsense Mutation (SNP) | VAF 18/67 reads (27%) | catalogued as COSV99444948; called by muse, mutect2, varscan2
- DNAH5 | c.3863G>A p.G1288E | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV54234064, COSV99444952; called by muse, mutect2, varscan2
- DNAH7 | c.10756C>T p.H3586Y | Missense Mutation (SNP) | VAF 77/133 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1241893715, COSV56761425; called by muse, mutect2, varscan2
- DNAH7 | c.8512C>T p.L2838F | Missense Mutation (SNP) | VAF 236/539 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56792612; called by muse, mutect2, varscan2
- DNAH7 | c.2935G>A p.E979K | Missense Mutation (SNP) | VAF 42/70 reads (60%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.622); catalogued as rs766259116, COSV56768023; called by muse, varscan2
- DNAH8 | c.1061C>T p.S354L | Missense Mutation (SNP) | VAF 19/93 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV100543276; called by muse, mutect2, varscan2
- DNAH8 | c.9259G>A p.D3087N | Missense Mutation (SNP) | VAF 23/100 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.207); catalogued as COSV59477220; called by muse, mutect2, varscan2
- DNAH9 | c.2539G>A p.E847K | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV52332598; called by muse, mutect2, varscan2
- DNAI1 | c.808G>A p.E270K | Missense Mutation (SNP) | VAF 12/56 reads (21%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.811); catalogued as COSV99646561; called by muse, mutect2, varscan2
- DOCK3 | c.1228G>A p.G410R | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1310914267, COSV99809087; called by muse, mutect2, varscan2
- DOCK3 | c.2570C>T p.P857L | Missense Mutation (SNP) | VAF 72/259 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs574674331, COSV99809090; called by muse, mutect2, varscan2
- DOCK4 | c.4063G>A p.E1355K | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.906); catalogued as COSV101445563; called by muse, mutect2, varscan2
- DOK6 | c.654G>A p.M218I | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.103); catalogued as rs753953695, COSV101234252; called by muse, mutect2, varscan2
- DPEP2 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs755283112, COSV99263055; called by muse, mutect2, varscan2
- DPP4 | c.791C>T p.P264L | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs749968268, COSV100858692; called by muse, mutect2, varscan2
- DPPA2 | c.251C>T p.P84L | Missense Mutation (SNP) | VAF 39/192 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.583); catalogued as rs771494904, COSV72118066; called by muse, mutect2, varscan2
- DPPA2 | c.58G>A p.D20N | Missense Mutation (SNP) | VAF 37/170 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV101524732; called by muse, mutect2, varscan2
- DPYD | c.2806G>A p.G936S | Missense Mutation (SNP) | VAF 80/136 reads (59%) | SIFT tolerated (0.25); PolyPhen benign (0.007); catalogued as COSV100928589; called by muse, mutect2, varscan2
- DPYS | c.1178G>A p.G393E | Missense Mutation (SNP) | VAF 36/103 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100037103; called by muse, mutect2, varscan2
- DPYS | c.520G>A p.E174K | Missense Mutation (SNP) | VAF 31/91 reads (34%) | SIFT deleterious (0.04); PolyPhen benign (0.083); catalogued as COSV100679250; called by muse, mutect2, varscan2
- DPYSL5 | c.827C>T p.A276V | Missense Mutation (SNP) | VAF 57/193 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV99981765; called by muse, mutect2, varscan2
- DSC1 | c.1540G>A p.E514K | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.026); catalogued as COSV99937167; called by muse, mutect2, varscan2
- DSC2 | c.1574G>A p.G525E | Missense Mutation (SNP) | VAF 48/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99199469; called by muse, mutect2, varscan2
- DSCAM | c.2591C>T p.S864F | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.998); catalogued as COSV68024846; called by muse, mutect2, varscan2
- DSCAM | c.1250T>G p.V417G | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV101259087; called by muse, mutect2, varscan2
- DSPP | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 10/52 reads (19%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.044); catalogued as rs368559431; called by muse, mutect2, varscan2
- DST | c.15881C>T p.S5294F (on ENST00000361203 / NM_001374722.1; = p.S2882F on NM_015548.5) | Missense Mutation (SNP) | VAF 29/80 reads (36%) | SIFT tolerated (0.7); PolyPhen benign (0.063); catalogued as COSV99751005; called by muse, mutect2, varscan2
- DTX1 | c.1276G>A p.G426S | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as rs1475134876, COSV99921409; called by muse, mutect2, varscan2
- DUSP13 | c.206A>G p.N69S | Missense Mutation (SNP) | VAF 18/67 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.917); catalogued as rs1326965957, COSV100403266; called by muse, mutect2, varscan2
- DYNC2H1 | c.2507T>C p.F836S | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as COSV100517524; called by muse, mutect2
- DYSF | c.3524C>T p.P1175L | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1251032024, COSV99244251; called by muse, mutect2, varscan2
- DZIP1 | c.1909C>T p.P637S (on ENST00000347108; = p.P618S on NM_014934.5) | Missense Mutation (SNP) | VAF 46/139 reads (33%) | SIFT tolerated (0.44); PolyPhen benign (0.009); catalogued as rs866164908, COSV100713998; called by muse, mutect2, varscan2
- EFCAB12 | c.248C>T p.P83L | Missense Mutation (SNP) | VAF 15/64 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.139); catalogued as COSV100394463; called by muse, mutect2, varscan2
- EFR3A | c.986C>T p.S329F | Missense Mutation (SNP) | VAF 16/48 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV54458322, COSV54459411, COSV99602442; called by muse, mutect2, varscan2
- EGF | c.1624G>A p.D542N | Missense Mutation (SNP) | VAF 34/78 reads (44%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.896); catalogued as COSV99490474; called by muse, mutect2, varscan2
- EIF2AK3 | c.2351C>T p.S784F | Missense Mutation (SNP) | VAF 74/360 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.246); catalogued as rs866676281, COSV57545247; called by muse, mutect2, varscan2
- ELAPOR1 | c.1354G>A p.E452K | Missense Mutation (SNP) | VAF 27/46 reads (59%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV100884403; called by muse, mutect2, varscan2
- ELMO1 | c.106G>A p.E36K | Missense Mutation (SNP) | VAF 104/417 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.074); catalogued as COSV60302824; called by muse, mutect2, varscan2
- ELMOD1 | c.883G>A p.D295N | Missense Mutation (SNP) | VAF 39/101 reads (39%) | SIFT tolerated (0.43); PolyPhen benign (0.124); catalogued as COSV99759647; called by muse, mutect2, varscan2
- ENPEP | c.813G>A p.W271* | Nonsense Mutation (SNP) | VAF 42/111 reads (38%) | catalogued as rs751393675, COSV99487031; called by muse, mutect2, varscan2
- ENPP2 | c.509C>T p.S170F | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50018801; called by muse, mutect2, varscan2
- EPB41L1 | c.2594G>A p.R865K | Missense Mutation (SNP) | VAF 59/132 reads (45%) | SIFT tolerated (1); PolyPhen probably damaging (0.994); catalogued as rs757167798, COSV52434151; called by muse, mutect2, varscan2
- EPHA1 | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99313505, COSV99313676; called by muse, mutect2
- EPHA2 | c.2585C>T p.P862L | Missense Mutation (SNP) | VAF 26/42 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767853703, COSV100626017; called by muse, mutect2, varscan2
- EPHA2 | c.2584C>T p.P862S | Missense Mutation (SNP) | VAF 25/41 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100626018; called by muse, mutect2, varscan2
- EPHA3 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 32/173 reads (18%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV100342801; called by muse, mutect2, varscan2
- EPHA6 | c.1219G>A p.E407K | Missense Mutation (SNP) | VAF 33/180 reads (18%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.992); catalogued as COSV67560246; called by muse, mutect2, varscan2
- EPN2 | c.1142C>T p.S381L | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.098); catalogued as rs184341621, COSV100127338; called by muse, mutect2, varscan2
- EPS15 | c.269C>T p.S90L | Missense Mutation (SNP) | VAF 34/54 reads (63%) | SIFT deleterious (0); PolyPhen benign (0.015); catalogued as COSV100869042; called by mutect2, varscan2
- ERAP2 | c.406G>A p.E136K | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.94); PolyPhen benign (0.003); catalogued as COSV101163500; called by muse, mutect2, varscan2
- ERCC6L | c.3004G>A p.E1002K | Missense Mutation (SNP) | VAF 33/60 reads (55%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as COSV100558992; called by muse, mutect2, varscan2
- ERICH3 | c.1594G>A p.D532N | Missense Mutation (SNP) | VAF 81/157 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs1292063195, COSV100443389; called by muse, mutect2, varscan2
- ERICH6 | c.409C>T p.P137S | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99901345; called by muse, mutect2, varscan2
- ESRP1 | c.958C>T p.L320F | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100619147; called by muse, mutect2, varscan2
- ETV1 | c.515C>T p.S172L | Missense Mutation (SNP) | VAF 54/201 reads (27%) | SIFT tolerated (0.66); PolyPhen benign (0.322); catalogued as rs761565850, COSV99622602; called by muse, mutect2, varscan2
- EXPH5 | c.1034C>T p.P345L | Missense Mutation (SNP) | VAF 30/55 reads (55%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.519); catalogued as rs1484269684, COSV99760907; called by muse, mutect2, varscan2
- EXT1 | c.634G>T p.G212C | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100983559; called by muse, mutect2, varscan2
- EYA2 | c.1082G>A p.G361E | Missense Mutation (SNP) | VAF 50/101 reads (50%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.663); catalogued as COSV57939747; called by muse, mutect2, varscan2
- EYA4 | c.1324G>A p.D442N (on ENST00000531901 / NM_001301013.1; = p.D436N on NM_004100.5) | Missense Mutation (SNP) | VAF 37/136 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV62058394; called by muse, mutect2, varscan2
- EZHIP | c.1310C>T p.S437F | Missense Mutation (SNP) | VAF 30/53 reads (57%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.918); catalogued as COSV100539464; called by muse, mutect2, varscan2
- F13A1 | c.500C>T p.P167L | Missense Mutation (SNP) | VAF 29/133 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.087); catalogued as rs746272012, CM146350, COSV53567658, COSV99342183; called by muse, mutect2, varscan2
- FAM135B | c.4180G>A p.E1394K | Missense Mutation (SNP) | VAF 38/183 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99418793; called by muse, mutect2, varscan2
- FAM135B | c.3218C>T p.S1073F | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52717578; called by muse, mutect2, varscan2
- FAM135B | c.2483C>T p.P828L | Missense Mutation (SNP) | VAF 18/81 reads (22%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as COSV52742540; called by muse, mutect2, varscan2
- FAM184A | c.256G>A p.E86K | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV100137366; called by muse, mutect2, varscan2
- FAM47A | c.1709C>T p.S570L | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT tolerated (0.57); PolyPhen benign (0.073); catalogued as rs1339397781, COSV60497528; called by muse, mutect2, varscan2
- FAM47C | c.35C>T p.S12F | Missense Mutation (SNP) | VAF 10/19 reads (53%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.592); catalogued as COSV63726658, COSV63727648; called by muse, mutect2, varscan2
- FAM47C | c.2465C>T p.S822F | Missense Mutation (SNP) | VAF 42/66 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100792272, COSV63723883; called by muse, mutect2, varscan2
- FAM83B | c.1390C>T p.R464W | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.07); catalogued as rs375679054, COSV60920972; called by muse, mutect2, varscan2
- FAT3 | c.11141A>G p.K3714R | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.956); catalogued as COSV99961830; called by muse, mutect2
- FAT4 | c.6127G>A p.D2043N | Missense Mutation (SNP) | VAF 32/131 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV100627214, COSV58671970; called by muse, mutect2, varscan2
- FAT4 | c.6700C>T p.R2234* | Nonsense Mutation (SNP) | VAF 35/111 reads (32%) | catalogued as COSV58715243; called by muse, mutect2, varscan2
- FAT4 | c.7448C>T p.P2483L | Missense Mutation (SNP) | VAF 31/95 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.346); catalogued as COSV100627216; called by muse, mutect2, varscan2
- FAT4 | c.11152C>T p.R3718C | Missense Mutation (SNP) | VAF 58/179 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs774217003, COSV100629752, COSV58686567; called by muse, mutect2, varscan2
- FBN2 | c.3589G>A p.D1197N | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV99324918; called by muse, mutect2, varscan2
- FBN3 | c.2416G>A p.D806N | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.537); catalogued as COSV99559757; called by muse, mutect2, varscan2
- FBN3 | c.1921G>A p.E641K | Missense Mutation (SNP) | VAF 20/57 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs755074368, COSV99559759; called by muse, mutect2, varscan2
- FBXO24 | c.4G>A p.G2S | Missense Mutation (SNP) | VAF 38/80 reads (48%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0); catalogued as COSV53824356; called by muse, mutect2, varscan2
- FBXO36 | c.139C>T p.R47* | Nonsense Mutation (SNP) | VAF 49/121 reads (40%) | catalogued as rs377169424, COSV99391414; called by muse, mutect2, varscan2
- FCHO1 | c.2456G>A p.R819K | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99405809; called by muse, mutect2, varscan2
- FCN3 | c.92-1G>A p.X31_splice | Splice Site (SNP) | VAF 21/35 reads (60%) | catalogued as COSV99585221; called by muse, varscan2
- FER1L6 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 56/177 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.02); catalogued as COSV67550586; called by muse, mutect2, varscan2
- FER1L6 | c.1391C>T p.S464L | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.014); catalogued as rs773368685, COSV67551378; called by muse, mutect2, varscan2
- FER1L6 | c.3956G>A p.G1319E | Missense Mutation (SNP) | VAF 28/127 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV67549400; called by muse, mutect2, varscan2
- FGA | c.1429G>A p.E477K | Missense Mutation (SNP) | VAF 48/153 reads (31%) | SIFT tolerated (0.09); PolyPhen benign (0.076); catalogued as COSV100119999, COSV57395980; called by muse, mutect2, varscan2
- FGD2 | c.1673G>A p.W558* | Nonsense Mutation (SNP) | VAF 40/126 reads (32%) | catalogued as COSV99235828; called by muse, mutect2, varscan2
- FGD5 | c.3337G>A p.E1113K | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.834); catalogued as COSV53256396; called by muse, mutect2, varscan2
- FGF23 | c.368G>A p.G123E | Missense Mutation (SNP) | VAF 50/154 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV99426222; called by muse, mutect2, varscan2
- FGF6 | c.462A>C p.Q154H | Missense Mutation (SNP) | VAF 28/90 reads (31%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99960142; called by muse, mutect2, varscan2
- FILIP1 | c.1457G>A p.R486K | Missense Mutation (SNP) | VAF 35/130 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99383838; called by muse, mutect2, varscan2
- FLG | c.3041C>T p.S1014F | Missense Mutation (SNP) | VAF 163/891 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); catalogued as COSV100910498; called by muse, mutect2, varscan2
- FLG | c.2308C>T p.H770Y | Missense Mutation (SNP) | VAF 151/708 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.009); catalogued as COSV100910499; called by muse, mutect2, varscan2
- FLG2 | c.4772G>A p.R1591K | Missense Mutation (SNP) | VAF 97/456 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.444); catalogued as COSV101166159, COSV66174369; called by muse, mutect2, varscan2
- FLG2 | c.290C>T p.S97L | Missense Mutation (SNP) | VAF 19/118 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101165590; called by muse, mutect2, varscan2
- FLT1 | c.941G>A p.R314K | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56723759, COSV56741933; called by muse, mutect2, varscan2
- FLT4 | c.1546A>G p.K516E | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV99985911; called by muse, mutect2, varscan2
- FMN2 | c.3793C>T p.P1265S | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100142687; called by muse, mutect2, varscan2
- FMN2 | c.4231G>A p.E1411K | Missense Mutation (SNP) | VAF 42/72 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs779310703, COSV60422534, COSV60455849; called by muse, mutect2, varscan2
- FMNL1 | c.327+1G>A p.X109_splice | Splice Site (SNP) | VAF 8/29 reads (28%) | catalogued as COSV100056150; called by muse, mutect2, varscan2
- FMO1 | c.718C>T p.Q240* | Nonsense Mutation (SNP) | VAF 71/117 reads (61%) | catalogued as COSV100707692, COSV100707694; called by muse, mutect2, varscan2
- FRAS1 | c.1948G>A p.G650R | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.563); catalogued as rs779070461, COSV99348157; called by muse, mutect2, varscan2
- FREM1 | c.4701C>A p.F1567L | Missense Mutation (SNP) | VAF 32/130 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); catalogued as COSV101083782; called by muse, mutect2, varscan2
- FREM1 | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.107); catalogued as COSV101083785, COSV66522846; called by muse, mutect2, varscan2
- FRMPD2 | c.2266+2T>A p.X756_splice | Splice Site (SNP) | VAF 4/16 reads (25%) | catalogued as COSV100563507; called by muse, mutect2
- FRMPD4 | c.826C>T p.P276S | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.476); catalogued as COSV101042126; called by muse, mutect2, varscan2
- FRY | c.3427C>T p.R1143C | Missense Mutation (SNP) | VAF 23/74 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs771312453, COSV66568488, COSV66570042; called by muse, mutect2, varscan2
- FRY | c.6407C>A p.S2136Y | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100968794; called by muse, mutect2, varscan2
- FSHR | c.472C>T p.H158Y | Missense Mutation (SNP) | VAF 28/50 reads (56%) | SIFT deleterious (0.04); PolyPhen benign (0.364); catalogued as rs1258816174, COSV100436323, COSV100436573; called by muse, mutect2, varscan2
- FSTL5 | c.509G>A p.G170D | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs773608761, COSV60186411; called by muse, mutect2, varscan2
- FSTL5 | c.508G>A p.G170S | Missense Mutation (SNP) | VAF 29/85 reads (34%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV60199713, COSV60240954; called by muse, mutect2, varscan2
- FUT9 | c.128C>T p.S43L | Missense Mutation (SNP) | VAF 35/123 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.122); catalogued as COSV100133061; called by muse, mutect2, varscan2
- GABPB1 | c.728C>T p.T243I | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT tolerated (0.18); PolyPhen benign (0.282); catalogued as COSV99589553; called by muse, mutect2, varscan2
- GABRA5 | c.1178C>T p.T393I | Missense Mutation (SNP) | VAF 8/21 reads (38%) | SIFT tolerated (0.27); PolyPhen benign (0.039); catalogued as rs1370523798, COSV100164734; called by muse, mutect2, varscan2
- GABRB2 | c.1139G>A p.G380E | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99195650; called by muse, mutect2, varscan2
- GABRG1 | c.238C>T p.R80C | Missense Mutation (SNP) | VAF 29/109 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1239800695, COSV54951118; called by muse, mutect2, varscan2
- GABRG2 | c.367G>A p.D123N | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV62722799; called by muse, mutect2, varscan2
- GALNS | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV51940832; called by muse, mutect2, varscan2
- GALNT9 | c.1779G>A p.M593I (on ENST00000328957 / NM_001122636.2; = p.M227I on NM_021808.3) | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV100201004; called by muse, mutect2, varscan2
- GATA4 | c.629A>C p.D210A | Missense Mutation (SNP) | VAF 30/132 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.416); catalogued as COSV100632785; called by muse, mutect2, varscan2
- GCKR | c.1237G>A p.D413N | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.945); catalogued as COSV53107318; called by muse, mutect2
- GCSAML | c.163A>G p.N55D | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.007); catalogued as COSV100825880; called by muse, mutect2, varscan2
- GDE1 | c.469C>A p.L157I | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.941); catalogued as COSV100783142, COSV62059846; called by muse, mutect2, varscan2
- GDF5 | c.835G>A p.D279N | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.926); catalogued as COSV65499598; called by muse, mutect2
- GGA2 | c.270G>A p.M90I | Missense Mutation (SNP) | VAF 14/70 reads (20%) | SIFT deleterious (0.05); PolyPhen benign (0.045); catalogued as COSV100564533; called by muse, mutect2, varscan2
- GIPC2 | c.410G>A p.G137D | Missense Mutation (SNP) | VAF 31/50 reads (62%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100883199; called by muse, mutect2, varscan2
- GLDC | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100393782; called by muse, mutect2
- GLI1 | c.488G>A p.G163E | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.05); PolyPhen benign (0.028); catalogued as rs1385280044, COSV57368372, COSV99953665; called by muse, mutect2, varscan2
- GLI1 | c.1967G>A p.R656K | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.708); catalogued as COSV99953666; called by muse, mutect2, varscan2
- GLI2 | c.3322G>A p.G1108R (on ENST00000361492 / NM_001374353.1; = p.G1125R on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.426); catalogued as rs753361318, COSV100082320; called by muse, mutect2, varscan2
- GLI2 | c.4526C>T p.S1509L (on ENST00000361492 / NM_001374353.1; = p.S1526L on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 60/258 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs781561335, COSV58037648; called by muse, mutect2, varscan2
- GLRA3 | c.167G>A p.G56E | Missense Mutation (SNP) | VAF 19/91 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as COSV99926948; called by muse, mutect2, varscan2
- GLT8D2 | c.593G>C p.G198A | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.999); catalogued as rs141452676, COSV100673982; called by muse, mutect2, varscan2
- GLYAT | c.872G>A p.W291* | Nonsense Mutation (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99557108; called by muse, mutect2, varscan2
- GNAO1 | c.706C>T p.H236Y | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.045); catalogued as COSV99340637; called by muse, mutect2
- GP2 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT tolerated (0.54); PolyPhen benign (0.017); catalogued as rs764673264, COSV56896617; called by muse, mutect2, varscan2
- GPATCH1 | c.2338C>T p.Q780* | Nonsense Mutation (SNP) | VAF 16/61 reads (26%) | catalogued as COSV50111459, COSV99403734; called by muse, mutect2, varscan2
- GPBP1 | c.821C>T p.S274F | Missense Mutation (SNP) | VAF 24/71 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV99302388; called by muse, mutect2, varscan2
- GPC6 | c.28C>T p.L10F | Missense Mutation (SNP) | VAF 28/76 reads (37%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV100988069; called by muse, mutect2, varscan2
- GPHN | c.2008C>T p.R670C (on ENST00000315266 / NM_001377519.1; = p.R703C on NM_020806.5) | Missense Mutation (SNP) | VAF 23/75 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1252936065, COSV100015339; called by muse, mutect2, varscan2
- GPLD1 | c.494G>A p.G165E | Missense Mutation (SNP) | VAF 29/69 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100014983; called by muse, mutect2, varscan2
- GPR12 | c.89C>T p.S30F | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.031); catalogued as COSV101197939, COSV67344201; called by muse, mutect2, varscan2
- GPR12 | c.88T>A p.S30T | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as COSV101197940; called by muse, mutect2, varscan2
- GPR149 | c.823T>C p.F275L | Missense Mutation (SNP) | VAF 14/84 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.001); catalogued as COSV101078109; called by muse, mutect2, varscan2
- GPR174 | c.752C>T p.P251L | Missense Mutation (SNP) | VAF 30/51 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.267); catalogued as COSV99337947, COSV99338382; called by muse, mutect2, varscan2
- GPR179 | c.2614G>A p.E872K (on ENST00000621958; = p.E871K on NM_001004334.4) | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as rs763351074; called by muse, mutect2, varscan2
- GPR63 | c.81G>A p.M27I | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100013131; called by muse, mutect2, varscan2
- GPSM1 | c.1721C>T p.P574L | Missense Mutation (SNP) | VAF 7/20 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs1564359111, COSV99395829, COSV99396153; called by muse, mutect2, varscan2
- GPX5 | c.239C>T p.P80L | Missense Mutation (SNP) | VAF 35/162 reads (22%) | SIFT tolerated (0.8); PolyPhen benign (0.02); catalogued as rs1308994203, COSV69079772; called by muse, mutect2, varscan2
- GRIA1 | c.1837C>T p.R613C | Missense Mutation (SNP) | VAF 22/57 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.874); catalogued as COSV53615819; called by muse, mutect2, varscan2
- GRIA2 | c.1975G>A p.D659N | Missense Mutation (SNP) | VAF 37/137 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99643009; called by muse, mutect2, varscan2
- GRIK3 | c.1198G>A p.D400N | Missense Mutation (SNP) | VAF 40/56 reads (71%) | SIFT tolerated (0.2); PolyPhen benign (0.058); catalogued as COSV100901311; called by muse, mutect2, varscan2
- GRIN2A | c.3134C>T p.S1045F | Missense Mutation (SNP) | VAF 52/157 reads (33%) | SIFT tolerated (0.05); PolyPhen benign (0.16); catalogued as COSV58025033; called by muse, mutect2, varscan2
- GRIP2 | c.1807G>C p.D603H (on ENST00000619221; = p.D506H on NM_001080423.4) | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99816933; called by muse, mutect2, varscan2
- GRK7 | c.68C>T p.S23L | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as rs762526012, COSV99379501; called by muse, mutect2, varscan2
- GUCY1A2 | c.847C>T p.P283S | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT tolerated (0.37); PolyPhen benign (0.095); catalogued as COSV99972681; called by muse, mutect2, varscan2
- GUCY2C | c.655G>A p.E219K | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.85); PolyPhen benign (0); catalogued as rs569162034, COSV53787281; called by muse, mutect2, varscan2
- H2AC16 | c.164T>G p.V55G | Missense Mutation (SNP) | VAF 51/173 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.976); catalogued as COSV100511097; called by muse, mutect2, varscan2
- HCRTR2 | c.1165C>T p.R389C | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs866820748, COSV63797066; called by muse, mutect2, varscan2
- HDAC9 | c.2141C>T p.P714L | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV101286208; called by muse, mutect2, varscan2
- HEATR3 | c.419C>T p.S140L | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.007); catalogued as COSV99589755; called by muse, mutect2, varscan2
- HEATR5A | c.2366C>T p.S789F | Missense Mutation (SNP) | VAF 46/147 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.28); catalogued as COSV101119570; called by muse, mutect2, varscan2
- HECW1 | c.332G>A p.W111* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV101222812; called by muse, mutect2, varscan2
- HECW1 | c.2513G>A p.R838Q | Missense Mutation (SNP) | VAF 45/70 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs753372751, COSV67822122; called by muse, mutect2, varscan2
- HERC6 | c.892C>T p.H298Y | Missense Mutation (SNP) | VAF 30/118 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52029660, COSV99910431; called by muse, mutect2, varscan2
- HFE | c.286C>T p.H96Y | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.103); catalogued as COSV58512886; called by muse, mutect2, varscan2
- HHIPL2 | c.881C>T p.S294L | Missense Mutation (SNP) | VAF 89/335 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV58564422; called by muse, mutect2, varscan2
- HMG20A | c.655C>T p.P219S | Missense Mutation (SNP) | VAF 21/86 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs762710203, COSV60314409; called by muse, mutect2, varscan2
- HPR | c.913G>A p.D305N | Missense Mutation (SNP) | VAF 35/104 reads (34%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.934); catalogued as rs1435453716, COSV99930767; called by muse, mutect2, varscan2
- HRH4 | c.173C>T p.A58V | Missense Mutation (SNP) | VAF 35/159 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1402881096, COSV99907712; called by muse, mutect2, varscan2
- HSD3B2 | c.427G>A p.E143K | Missense Mutation (SNP) | VAF 88/135 reads (65%) | SIFT deleterious (0.01); PolyPhen benign (0.297); catalogued as COSV65593228, COSV65593903; called by muse, mutect2, varscan2
- HTATSF1 | c.913C>T p.L305F | Missense Mutation (SNP) | VAF 23/44 reads (52%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.886); catalogued as COSV99511399; called by muse, mutect2, varscan2
- HYDIN | c.8056G>A p.E2686K | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0.311); catalogued as COSV59253351; called by muse, mutect2, varscan2
- IARS1 | c.1963C>T p.P655S | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1486097025, COSV100986776; called by muse, mutect2, varscan2
- IBTK | c.562C>T p.H188Y | Missense Mutation (SNP) | VAF 24/65 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1291291436, COSV100090016; called by muse, mutect2, varscan2
- IGHE | c.707C>T p.T236M | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.116); catalogued as rs372237164; called by muse, mutect2, varscan2
- IGKC | c.16C>T p.P6S | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs773475625; called by mutect2, varscan2
- IGSF1 | c.544G>A p.A182T | Missense Mutation (SNP) | VAF 37/64 reads (58%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1381471947, COSV100811824; called by muse, mutect2, varscan2
- IGSF10 | c.3868C>T p.P1290S | Missense Mutation (SNP) | VAF 70/177 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.087); catalogued as COSV99176616; called by muse, mutect2, varscan2
- IGSF21 | c.1145G>A p.G382E | Missense Mutation (SNP) | VAF 30/49 reads (61%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99243706; called by muse, mutect2, varscan2
- IL18RAP | c.305C>T p.P102L | Missense Mutation (SNP) | VAF 47/102 reads (46%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV51828896; called by muse, mutect2, varscan2
- IL1RAP | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 60/125 reads (48%) | SIFT deleterious (0.01); PolyPhen benign (0.44); catalogued as COSV50765863; called by muse, mutect2, varscan2
- IL1RAPL2 | c.244G>A p.D82N | Missense Mutation (SNP) | VAF 26/52 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.767); catalogued as COSV61163588; called by muse, mutect2, varscan2
- IL24 | c.481T>A p.S161T | Missense Mutation (SNP) | VAF 21/97 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV99686374; called by muse, mutect2, varscan2
- IL27 | c.436G>A p.D146N | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.95); catalogued as rs775285948, COSV60490993; called by muse, mutect2, varscan2
- IL36B | c.97C>T p.P33S | Missense Mutation (SNP) | VAF 11/45 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as rs868633800, COSV99382464; called by muse, mutect2, varscan2
- INPP5F | c.185C>T p.P62L | Missense Mutation (SNP) | VAF 19/46 reads (41%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV62823443; called by muse, mutect2, varscan2
- INSRR | c.1166C>T p.A389V | Missense Mutation (SNP) | VAF 186/328 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.914); catalogued as COSV100947133; called by muse, mutect2, varscan2
- INTS1 | c.3035C>T p.P1012L | Missense Mutation (SNP) | VAF 23/96 reads (24%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as rs776193013, COSV101247413; called by muse, mutect2, varscan2
- INTS1 | c.657C>G p.D219E | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT tolerated (0.69); PolyPhen benign (0.104); catalogued as COSV101247416, COSV101248430; called by muse, mutect2, varscan2
- INTU | c.599G>T p.G200V | Missense Mutation (SNP) | VAF 30/120 reads (25%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV99611427; called by muse, mutect2, varscan2
- IRF5 | c.136C>T p.P46S | Missense Mutation (SNP) | VAF 31/67 reads (46%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.906); catalogued as COSV50859865; called by muse, mutect2, varscan2
- ITGA5 | c.1172G>A p.R391Q | Missense Mutation (SNP) | VAF 14/75 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs747517291, COSV99516279; called by muse, varscan2
- ITGA8 | c.265G>A p.E89K | Missense Mutation (SNP) | VAF 31/100 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV65226342; called by muse, mutect2, varscan2
- ITGB3 | c.1184C>T p.S395F | Missense Mutation (SNP) | VAF 44/121 reads (36%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV71385300; called by muse, mutect2, varscan2
- ITGB4 | c.3382G>A p.G1128S | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0.022); catalogued as rs1389787659, COSV99563349; called by muse, mutect2, varscan2
- ITK | c.472C>T p.P158S | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs752554340, COSV70065117; called by muse, mutect2, varscan2
- ITLN1 | c.259G>A p.E87K | Missense Mutation (SNP) | VAF 18/105 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58273735; called by muse, mutect2, varscan2
- ITPKC | c.1517C>T p.P506L | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT tolerated (0.83); PolyPhen benign (0.245); catalogued as COSV99648444; called by muse, mutect2, varscan2
- ITSN1 | c.3942G>A p.M1314I | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.14); PolyPhen benign (0.238); catalogued as COSV101181213; called by muse, mutect2, varscan2
- JAG2 | c.3502C>T p.P1168S | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.49); PolyPhen benign (0.212); catalogued as COSV59311651, COSV59312808; called by muse, mutect2, varscan2
- JAK3 | c.1838G>A p.R613Q | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.05); PolyPhen benign (0.165); catalogued as rs1257320432, COSV71686564; called by muse, mutect2, varscan2
- JARID2 | c.3136-2A>C p.X1046_splice | Splice Site (SNP) | VAF 59/281 reads (21%) | catalogued as COSV100521276; called by muse, mutect2, varscan2
- JPH1 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 47/177 reads (27%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs1228915983, COSV60612154; called by muse, mutect2, varscan2
- KALRN | c.3729G>A p.E1243= | Splice Region (SNP) | VAF 19/50 reads (38%) | catalogued as COSV99562093; called by muse, mutect2, varscan2
- KALRN | c.5270C>T p.S1757F (on ENST00000360013 / NM_001024660.4; = p.S60F on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 29/84 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.026); catalogued as COSV99361001; called by muse, mutect2, varscan2
- KANK3 | c.2140A>G p.T714A | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100035408; called by muse, mutect2, varscan2
- KANK4 | c.1195C>T p.H399Y | Missense Mutation (SNP) | VAF 62/111 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.062); catalogued as rs1485212258, COSV62985916; called by muse, mutect2, varscan2
- KAT6B | c.4499C>T p.P1500L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.003); catalogued as COSV99767334; called by muse, mutect2, varscan2
- KCNA1 | c.472G>A p.E158K | Missense Mutation (SNP) | VAF 34/92 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV101230107, COSV101230165, COSV101230395; called by muse, mutect2, varscan2
- KCNB2 | c.2531C>T p.P844L | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT tolerated, low confidence (0.66); PolyPhen benign (0.021); catalogued as COSV101578651; called by muse, mutect2, varscan2
- KCNH5 | c.344G>A p.R115K | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT tolerated (0.52); PolyPhen possibly damaging (0.557); catalogued as COSV100525334; called by muse, mutect2, varscan2
- KCNH8 | c.919T>G p.L307V | Missense Mutation (SNP) | VAF 34/141 reads (24%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); catalogued as COSV100108424; called by muse, mutect2, varscan2
- KCNH8 | c.3185C>T p.S1062F | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.991); catalogued as COSV60471810; called by muse, mutect2, varscan2
- KCNK1 | c.868C>T p.Q290* | Nonsense Mutation (SNP) | VAF 16/74 reads (22%) | catalogued as COSV64035642; called by muse, mutect2, varscan2
- KCNMB3 | c.14G>A p.S5N | Missense Mutation (SNP) | VAF 17/43 reads (40%) | SIFT tolerated (0.05); PolyPhen benign (0.038); catalogued as COSV100566571; called by muse, mutect2, varscan2
- KCNT1 | c.653C>T p.P218L (on ENST00000488444; = p.P237L on NM_020822.3) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.805); catalogued as COSV99704944; called by muse, mutect2, varscan2
- KCNT2 | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 86/167 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV99651491; called by muse, mutect2, varscan2
- KCNV1 | c.298G>A p.E100K | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.898); catalogued as rs1000789197, COSV52085311, COSV52087728; called by muse, mutect2, varscan2
- KDM1B | c.46C>T p.H16Y | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.095); catalogued as rs200534471, COSV99923917, COSV99923970; called by muse, mutect2, varscan2
- KIAA1210 | c.4520C>T p.P1507L | Missense Mutation (SNP) | VAF 12/16 reads (75%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.61); catalogued as COSV101273914; called by muse, mutect2, varscan2
- KIAA1217 | c.3154C>T p.P1052S | Missense Mutation (SNP) | VAF 9/31 reads (29%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV100286199; called by muse, mutect2, varscan2
- KIAA1522 | c.1559C>T p.S520L (on ENST00000373480 / NM_001198972.2; = p.S579L on NM_020888.3) | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1247500808, COSV99614121; called by muse, mutect2, varscan2
- KIF16B | c.3673C>T p.R1225* | Nonsense Mutation (SNP) | VAF 62/204 reads (30%) | catalogued as rs757912986, COSV100733757; called by muse, mutect2, varscan2
- KIF2B | c.1897G>A p.D633N | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT tolerated (0.08); PolyPhen benign (0.144); catalogued as rs759204622, COSV52130695; called by muse, mutect2, varscan2
- KIFAP3 | c.422T>G p.L141* | Nonsense Mutation (SNP) | VAF 42/217 reads (19%) | catalogued as rs1394688600, COSV100846701; called by muse, mutect2, varscan2
- KL | c.2823G>A p.M941I | Missense Mutation (SNP) | VAF 44/163 reads (27%) | SIFT tolerated (0.63); PolyPhen benign (0.001); catalogued as COSV101199002; called by muse, mutect2, varscan2
- KLHDC7A | c.490G>A p.E164K | Missense Mutation (SNP) | VAF 35/55 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.413); catalogued as COSV101272716; called by muse, mutect2, varscan2
- KLHL40 | c.172T>A p.F58I | Missense Mutation (SNP) | VAF 18/36 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99825320; called by muse, mutect2, varscan2
- KLHL6 | c.1639G>A p.E547K | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT tolerated (1); PolyPhen benign (0.251); catalogued as COSV58064346, COSV58064976; called by muse, mutect2, varscan2
- KLRC1 | c.4G>A p.D2N | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV100760733; called by muse, mutect2
- KNDC1 | c.2950C>A p.R984S | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT tolerated (0.76); PolyPhen benign (0.001); catalogued as rs774894229, COSV100463310; called by muse, varscan2
- KRT10 | c.436G>A p.E146K | Missense Mutation (SNP) | VAF 25/71 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.874); catalogued as COSV99509895; called by muse, mutect2, varscan2
- KRT20 | c.451G>A p.A151T | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.377); catalogued as rs1423011210, COSV99391313; called by muse, mutect2, varscan2
- KRT34 | c.536C>A p.A179D | Missense Mutation (SNP) | VAF 29/91 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV101222545; called by muse, mutect2, varscan2
- KRT37 | c.316G>A p.E106K | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV56658833; called by muse, mutect2, varscan2
- KRTAP10-8 | c.701C>T p.S234F | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.796); catalogued as COSV58166636; called by muse, mutect2, varscan2
- KRTAP9-2 | c.171T>G p.C57W | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100893110; called by muse, mutect2, varscan2
- KSR2 | c.1855G>A p.E619K | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.958); catalogued as COSV100194173; called by muse, mutect2, varscan2
- KTN1 | c.3119T>G p.M1040R | Missense Mutation (SNP) | VAF 13/45 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.628); catalogued as COSV100618299; called by muse, mutect2, varscan2
- LAMC2 | c.79+1G>A p.X27_splice | Splice Site (SNP) | VAF 5/17 reads (29%) | catalogued as rs1409174019, COSV99917021; called by muse, mutect2, varscan2
- LATS1 | c.1597C>A p.P533T | Missense Mutation (SNP) | VAF 34/136 reads (25%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV53594728, COSV99485241; called by muse, mutect2, varscan2
- LDLR | c.448C>T p.P150S | Missense Mutation (SNP) | VAF 51/197 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.207); catalogued as COSV52945365; called by muse, mutect2, varscan2
- LHX9 | c.490T>A p.C164S | Missense Mutation (SNP) | VAF 62/100 reads (62%) | SIFT deleterious (0.04); PolyPhen benign (0.119); catalogued as COSV100435616; called by muse, mutect2, varscan2
- LIFR | c.3140C>T p.S1047F | Missense Mutation (SNP) | VAF 35/128 reads (27%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1211064435, COSV99663231; called by muse, mutect2, varscan2
- LILRA4 | c.1489G>A p.E497K | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.953); catalogued as rs767985779, COSV99392877; called by muse, mutect2, varscan2
- LILRA4 | c.187G>A p.E63K | Missense Mutation (SNP) | VAF 38/150 reads (25%) | SIFT deleterious (0.04); PolyPhen benign (0.069); catalogued as COSV99392879, COSV99392966; called by muse, mutect2, varscan2
- LILRB1 | c.665C>T p.P222L (on ENST00000427581; = p.P186L on NM_006669.6) | Missense Mutation (SNP) | VAF 32/135 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1435007627, COSV61116864; called by muse, mutect2, varscan2
- LIPI | c.797G>A p.G266E | Missense Mutation (SNP) | VAF 13/49 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs867097666, COSV60709067; called by muse, mutect2, varscan2
- LIPJ | c.976G>A p.E326K | Missense Mutation (SNP) | VAF 26/96 reads (27%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV64245572, COSV64246038; called by muse, mutect2, varscan2
- LMO7 | c.2324C>T p.S775F (on ENST00000357063; = p.S456F on NM_005358.5) | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV100412423; called by muse, mutect2, varscan2
- LMOD3 | c.319G>A p.E107K | Missense Mutation (SNP) | VAF 11/33 reads (33%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs1335057595, COSV101341970, COSV70456174; called by muse, mutect2, varscan2
- LONP2 | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 7/33 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53526598; called by muse, mutect2, varscan2
- LONP2 | c.962C>T p.P321L | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99588817; called by muse, mutect2, varscan2
- LPP | c.1051C>T p.P351S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.169); catalogued as COSV100446295; called by muse, mutect2, varscan2
- LRP2 | c.4790T>G p.I1597S | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV99786510; called by muse, mutect2, varscan2
- LRRC17 | c.691C>T p.P231S | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT tolerated (0.91); PolyPhen benign (0); catalogued as COSV50868628; called by muse, mutect2, varscan2
- LRRC19 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 25/134 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.663); catalogued as COSV101195768, COSV101195816; called by muse, mutect2, varscan2
- LRRC25 | c.91G>A p.D31N | Missense Mutation (SNP) | VAF 10/30 reads (33%) | SIFT tolerated (0.9); PolyPhen benign (0); catalogued as COSV59115812; called by muse, mutect2, varscan2
- LRRC3B | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV101185673; called by muse, mutect2, varscan2
- LRRC3B | c.485C>T p.S162F | Missense Mutation (SNP) | VAF 22/45 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.093); catalogued as COSV101185674; called by muse, mutect2, varscan2
- LRRTM4 | c.785G>A p.G262E | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1316885554, COSV69143545; called by muse, mutect2, varscan2
- LRTM1 | c.906G>A p.M302I | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.449); catalogued as COSV99835860; called by muse, mutect2, varscan2
- LSM14A | c.337C>T p.P113S | Missense Mutation (SNP) | VAF 41/157 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.986); catalogued as COSV101471663; called by muse, varscan2
- LVRN | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.653); catalogued as COSV100773324; called by muse, mutect2, varscan2
- MACC1 | c.2305G>A p.E769K | Missense Mutation (SNP) | VAF 17/117 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV60544984; called by muse, mutect2, varscan2
- MACROD2 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.987); catalogued as rs778184364, COSV53987529; called by muse, mutect2, varscan2
- MAGEA8 | c.382C>T p.Q128* | Nonsense Mutation (SNP) | VAF 35/63 reads (56%) | catalogued as COSV54064281; called by muse, mutect2, varscan2
- MAGEC1 | c.2159C>T p.S720F | Missense Mutation (SNP) | VAF 54/90 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV53571884, COSV99596794; called by muse, mutect2, varscan2
- MAGEC3 | c.1019G>A p.G340E | Missense Mutation (SNP) | VAF 35/56 reads (63%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as COSV68923945; called by muse, mutect2, varscan2
- MAN1A1 | c.323G>A p.G108E | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100870294; called by muse, mutect2, varscan2
- MAP1A | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.661); catalogued as COSV100288070; called by muse, mutect2, varscan2
- MAP3K10 | c.562G>A p.G188S | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); catalogued as rs1171671367, COSV99453974; called by muse, mutect2, varscan2
- MAP3K10 | c.563G>A p.G188D | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.74); catalogued as COSV53425143; called by muse, mutect2, varscan2
- MAP3K19 | c.1262C>T p.S421L | Missense Mutation (SNP) | VAF 62/144 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.088); catalogued as COSV100208052; called by muse, mutect2, varscan2
- MAP3K19 | c.362C>T p.S121F | Missense Mutation (SNP) | VAF 62/141 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.832); catalogued as COSV100208053; called by muse, mutect2, varscan2
- MAP3K5 | c.1838G>A p.S613N | Missense Mutation (SNP) | VAF 57/176 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as COSV100752478; called by muse, mutect2, varscan2
- MAP3K8 | c.850C>T p.P284S | Missense Mutation (SNP) | VAF 34/79 reads (43%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV99551933; called by muse, mutect2, varscan2
- MAP3K9 | c.1111C>T p.P371S | Missense Mutation (SNP) | VAF 14/69 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101173460; called by muse, mutect2, varscan2
- MAPK4 | c.1006G>A p.D336N | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT tolerated (0.05); PolyPhen benign (0.089); catalogued as rs757002674, COSV68542156; called by muse, mutect2, varscan2
- MARF1 | c.2840C>T p.P947L | Missense Mutation (SNP) | VAF 19/61 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100705600; called by muse, mutect2, varscan2
- MBD5 | c.2356C>T p.Q786* | Nonsense Mutation (SNP) | VAF 83/180 reads (46%) | catalogued as COSV101289938; called by muse, mutect2, varscan2
- MED10 | c.352C>T p.P118S | Missense Mutation (SNP) | VAF 22/89 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99740179; called by muse, mutect2, varscan2
- MEF2D | c.331C>T p.P111S | Missense Mutation (SNP) | VAF 35/195 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.929); catalogued as COSV100559821; called by muse, mutect2, varscan2
- MERTK | c.1605G>A p.G535= | Splice Region (SNP) | VAF 17/116 reads (15%) | catalogued as COSV99774041; called by muse, mutect2, varscan2
- MFHAS1 | c.1393G>A p.A465T | Missense Mutation (SNP) | VAF 26/78 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV99359161; called by muse, mutect2, varscan2
- MGAM | c.2903C>T p.P968L | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs1406912099, COSV101527371; called by muse, mutect2, varscan2
- MIA2 | c.589G>A p.E197K | Missense Mutation (SNP) | VAF 19/79 reads (24%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.765); catalogued as COSV99696615; called by muse, mutect2, varscan2
- MICAL2 | c.3350C>T p.P1117L | Missense Mutation (SNP) | VAF 32/96 reads (33%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.997); catalogued as rs1272607360, COSV99816699; called by muse, mutect2, varscan2
- MICALL2 | c.1483C>T p.P495S | Missense Mutation (SNP) | VAF 122/227 reads (54%) | SIFT tolerated (0.13); PolyPhen benign (0.018); catalogued as rs757116054, COSV52518295; called by muse, mutect2, varscan2
- MIDN | c.1243C>T p.P415S | Missense Mutation (SNP) | VAF 9/20 reads (45%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.996); catalogued as COSV56294853; called by muse, mutect2, varscan2
- MINDY4 | c.1074G>A p.R358= | Splice Region (SNP) | VAF 52/182 reads (29%) | catalogued as COSV54675770; called by muse, mutect2, varscan2
- MMP12 | c.1100G>A p.S367N | Missense Mutation (SNP) | VAF 7/34 reads (21%) | SIFT tolerated (0.32); PolyPhen benign (0.003); catalogued as COSV100404816; called by muse, mutect2, varscan2
- MMP8 | c.112G>A p.E38K | Missense Mutation (SNP) | VAF 19/63 reads (30%) | SIFT tolerated (0.17); PolyPhen benign (0.074); catalogued as COSV52632873, COSV99368594; called by muse, mutect2, varscan2
- MPEG1 | c.1984G>A p.V662M | Missense Mutation (SNP) | VAF 29/117 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.01); catalogued as COSV99914995; called by muse, mutect2, varscan2
- MRAP2 | c.101C>T p.S34F | Missense Mutation (SNP) | VAF 22/70 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV57632375; called by muse, mutect2, varscan2
- MRTFB | c.3133C>T p.P1045S (on ENST00000571589 / NM_001365412.2; = p.P995S on NM_014048.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.6); PolyPhen benign (0.012); catalogued as COSV100371267, COSV57960082; called by muse, mutect2, varscan2
- MS4A2 | c.629G>A p.G210E | Missense Mutation (SNP) | VAF 18/53 reads (34%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV54013625; called by muse, mutect2, varscan2
- MS4A5 | c.269G>A p.W90* | Nonsense Mutation (SNP) | VAF 33/135 reads (24%) | catalogued as COSV100280903, COSV55742694; called by muse, mutect2
- MST1R | c.3167C>T p.S1056F | Missense Mutation (SNP) | VAF 111/234 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99617701; called by muse, mutect2, varscan2
- MTHFR | c.1024G>A p.D342N | Missense Mutation (SNP) | VAF 38/61 reads (62%) | SIFT tolerated (0.12); PolyPhen benign (0.01); catalogued as COSV100928221; called by muse, mutect2, varscan2
- MTO1 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.826); catalogued as rs1318798871, COSV100940315, COSV100940426; called by muse, mutect2, varscan2
- MUC16 | c.33833C>T p.P11278L | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.047); catalogued as rs976289493, COSV101198087; called by muse, mutect2, varscan2
- MUC16 | c.32065G>A p.E10689K | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.479); catalogued as COSV67462061, COSV67462565; called by muse, mutect2, varscan2
- MUC16 | c.23738G>A p.G7913E | Missense Mutation (SNP) | VAF 33/90 reads (37%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.006); catalogued as rs1337882133, COSV67448062, COSV67495977; called by muse, mutect2, varscan2
- MUC16 | c.20843C>T p.S6948F | Missense Mutation (SNP) | VAF 53/168 reads (32%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.02); catalogued as COSV67458145; called by muse, mutect2, varscan2
- MUC16 | c.14218G>A p.D4740N | Missense Mutation (SNP) | VAF 32/115 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.005); catalogued as rs1214687860, COSV67506815; called by muse, mutect2, varscan2
- MUC16 | c.12584C>T p.S4195F | Missense Mutation (SNP) | VAF 14/57 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.163); catalogued as COSV101198090, COSV67463278; called by muse, mutect2, varscan2
- MUC16 | c.4469C>T p.P1490L | Missense Mutation (SNP) | VAF 61/187 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); catalogued as COSV101197414; called by muse, mutect2, varscan2
- MUC16 | c.2078G>A p.G693E | Missense Mutation (SNP) | VAF 19/65 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.151); catalogued as COSV67446876; called by muse, mutect2, varscan2
- MUC17 | c.12616C>T p.H4206Y | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV60298510; called by muse, mutect2, varscan2
- MUC4 | c.14582C>T p.P4861L (on ENST00000463781 / NM_018406.7; = p.P625L on NM_004532.6) | Missense Mutation (SNP) | VAF 31/141 reads (22%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.007); catalogued as COSV100203507; called by muse, mutect2, varscan2
- MUSK | c.602C>T p.S201F | Missense Mutation (SNP) | VAF 23/67 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99503646; called by muse, mutect2, varscan2
- MUSK | c.739G>A p.E247K | Missense Mutation (SNP) | VAF 37/89 reads (42%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.963); catalogued as COSV51883929; called by muse, mutect2, varscan2
- MXRA5 | c.6784A>T p.K2262* | Nonsense Mutation (SNP) | VAF 28/49 reads (57%) | catalogued as COSV99475713; called by muse, mutect2, varscan2
- MXRA5 | c.5017C>T p.P1673S | Missense Mutation (SNP) | VAF 82/128 reads (64%) | SIFT tolerated (0.13); PolyPhen benign (0.026); catalogued as COSV54249320; called by muse, mutect2, varscan2
- MYB | c.1301C>T p.P434L | Missense Mutation (SNP) | VAF 20/75 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV100214539; called by muse, mutect2, varscan2
- MYH1 | c.4543G>A p.D1515N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.901); catalogued as COSV99874881; called by muse, mutect2, varscan2
- MYH1 | c.4313G>A p.R1438K | Missense Mutation (SNP) | VAF 30/122 reads (25%) | SIFT tolerated (0.22); PolyPhen benign (0.074); catalogued as COSV99874884; called by muse, mutect2, varscan2
- MYH2 | c.683C>T p.P228L | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.901); catalogued as rs1389727909, COSV55435196; called by muse, mutect2, varscan2
- MYH4 | c.3109G>A p.D1037N | Missense Mutation (SNP) | VAF 54/224 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.796); catalogued as rs143090408, COSV55113829, COSV99701560; called by muse, varscan2
- MYH6 | c.4834G>A p.E1612K | Missense Mutation (SNP) | VAF 22/114 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1417882969, COSV62450313; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYLK | c.2882G>A p.G961E | Missense Mutation (SNP) | VAF 44/87 reads (51%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as rs764696619, COSV100658499; called by muse, varscan2
- MYLK | c.2854G>A p.D952N | Missense Mutation (SNP) | VAF 24/105 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); catalogued as rs971096950, COSV60615171; called by muse, varscan2
- MYLK3 | c.1619C>T p.P540L | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.29); PolyPhen benign (0.029); catalogued as COSV101189046; called by muse, mutect2, varscan2
- MYO15A | c.601G>A p.E201K | Missense Mutation (SNP) | VAF 5/32 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.668); catalogued as rs1313642761, COSV52757932; called by muse, mutect2, varscan2
- MYO15A | c.6619C>T p.P2207S | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99231142; called by muse, mutect2, varscan2
- MYO18B | c.4549G>A p.E1517K | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs370120344; called by muse, mutect2, varscan2
- MYO18B | c.5038G>A p.E1680K | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as rs749666378, COSV59130355, COSV59131815; called by muse, mutect2
- MYOCD | c.2606C>T p.S869L | Missense Mutation (SNP) | VAF 14/54 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.084); catalogued as COSV58496972; called by muse, mutect2, varscan2
- N4BP2 | c.3388A>T p.T1130S | Missense Mutation (SNP) | VAF 17/84 reads (20%) | SIFT tolerated (0.48); PolyPhen benign (0.212); catalogued as COSV99788191; called by muse, mutect2, varscan2
- NAALADL2 | c.1093G>A p.E365K | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.23); PolyPhen benign (0.007); catalogued as COSV101379889; called by muse, mutect2
- NAV3 | c.874G>A p.E292K | Missense Mutation (SNP) | VAF 23/85 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1440244361, COSV57063645; called by muse, mutect2, varscan2
- NBEAL2 | c.6667C>T p.P2223S | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.791); catalogued as COSV52761195; called by muse, mutect2, varscan2
- NBPF9 | c.1697C>T p.S566L | Missense Mutation (SNP) | VAF 113/618 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.066); catalogued as rs782190347, COSV56018403; called by muse, mutect2, varscan2
- NCAN | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.039); catalogued as COSV53059374; called by muse, mutect2, varscan2
- NCKAP1L | c.2543G>A p.G848D | Missense Mutation (SNP) | VAF 64/242 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99514453; called by muse, mutect2, varscan2
- NDNF | c.1075G>A p.G359R | Missense Mutation (SNP) | VAF 36/113 reads (32%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.99); catalogued as rs868169962, COSV65632995; called by muse, mutect2, varscan2
- NDNF | c.451C>T p.L151F | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.11); PolyPhen benign (0.043); catalogued as COSV101113089; called by muse, mutect2, varscan2
- NDST4 | c.2123G>A p.R708Q | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.536); catalogued as rs764667030, COSV52110213, COSV52127649; called by muse, mutect2, varscan2
- NEK2 | c.934C>T p.Q312* | Nonsense Mutation (SNP) | VAF 81/340 reads (24%) | catalogued as COSV100878509; called by muse, mutect2, varscan2
- NF1 | c.6643-2A>T p.X2215_splice (on ENST00000358273 / NM_001042492.3; = p.X2194_splice on NM_000267.3) | Splice Site (SNP) | VAF 11/40 reads (28%) | catalogued as CS1311543, COSV100646014; called by muse, varscan2
- NFATC1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 20/61 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV53706274, COSV99500564; called by muse, mutect2, varscan2
- NIPAL1 | c.314-1G>A p.X105_splice | Splice Site (SNP) | VAF 14/51 reads (27%) | catalogued as rs1447958598, COSV99784282; called by muse, mutect2, varscan2
- NKAPL | c.587G>A p.R196K | Missense Mutation (SNP) | VAF 20/89 reads (22%) | SIFT tolerated (0.7); PolyPhen benign (0.006); catalogued as COSV59199307; called by muse, mutect2, varscan2
- NLGN4X | c.1823C>T p.S608L | Missense Mutation (SNP) | VAF 43/74 reads (58%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.558); catalogued as COSV52005738; called by muse, mutect2, varscan2
- NLGN4Y | c.1555C>T p.L519F | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV100196357; called by muse, mutect2, varscan2
- NLRP1 | c.1462G>A p.E488K | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT tolerated (0.26); PolyPhen benign (0.114); catalogued as rs1254455800, COSV52558007; called by muse, mutect2, varscan2
- NLRP1 | c.1010G>A p.G337E | Missense Mutation (SNP) | VAF 52/178 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99332930, COSV99333861; called by muse, mutect2, varscan2
- NLRP10 | c.478G>A p.E160K | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT tolerated (0.2); PolyPhen benign (0.387); catalogued as rs866417661, COSV60781132; called by muse, mutect2, varscan2
- NLRP2 | c.452G>A p.G151E | Missense Mutation (SNP) | VAF 23/72 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV54752116; called by muse, mutect2, varscan2
- NLRP9 | c.268G>A p.E90K | Missense Mutation (SNP) | VAF 175/598 reads (29%) | SIFT tolerated (0.29); PolyPhen benign (0.223); catalogued as COSV60460416; called by muse, mutect2, varscan2
- NMBR | c.616G>A p.E206K | Missense Mutation (SNP) | VAF 31/118 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.026); catalogued as COSV99237086; called by muse, mutect2, varscan2
- NMI | c.266C>T p.S89L | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT tolerated (0.39); PolyPhen benign (0.089); catalogued as rs753174267, COSV54638529; called by muse, mutect2, varscan2
- NOL11 | c.1801C>T p.L601F | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.902); catalogued as rs1488015779, COSV53522510, COSV99474831; called by muse, mutect2, varscan2
- NOS1 | c.2195G>A p.R732Q | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.838); catalogued as rs1029861467, COSV100500011; called by muse, mutect2, varscan2
- NOX4 | c.767C>T p.S256L | Missense Mutation (SNP) | VAF 24/93 reads (26%) | SIFT tolerated (0.36); PolyPhen benign (0.005); catalogued as COSV54454397, COSV99629576; called by muse, mutect2, varscan2
- NPAP1 | c.3293C>T p.S1098L | Missense Mutation (SNP) | VAF 101/177 reads (57%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.048); catalogued as COSV100274772; called by muse, mutect2, varscan2
- NPFFR2 | c.1412G>A p.S471N | Missense Mutation (SNP) | VAF 28/98 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100440298; called by muse, mutect2, varscan2
- NR1H4 | c.280G>A p.G94R (on ENST00000551379 / NM_001206993.2; = p.G84R on NM_005123.4) | Missense Mutation (SNP) | VAF 26/72 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.786); catalogued as COSV99500004; called by muse, mutect2, varscan2
- NT5E | c.347G>A p.G116E | Missense Mutation (SNP) | VAF 18/45 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1206176412, COSV100003867; called by muse, mutect2, varscan2
- NYAP2 | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 14/28 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.048); catalogued as rs776044334, COSV99795716; called by muse, varscan2
- OBSCN | c.11101G>A p.E3701K | Missense Mutation (SNP) | VAF 27/84 reads (32%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.975); catalogued as COSV99472520; called by muse, mutect2, varscan2
- ODF4 | c.591G>A p.A197= | Splice Region (SNP) | VAF 21/71 reads (30%) | catalogued as rs777173403, COSV100071798; called by muse, mutect2, varscan2
- OGDHL | c.856G>A p.E286K | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0.086); catalogued as rs771174825, COSV65102591; called by muse, mutect2, varscan2
- OLFM4 | c.419G>A p.R140Q | Missense Mutation (SNP) | VAF 16/64 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as rs753080611, COSV99524183; called by muse, mutect2, varscan2
- OR10A3 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 33/86 reads (38%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.872); catalogued as rs150357760, COSV100660211; called by muse, mutect2, varscan2
- OR10A4 | c.631C>T p.P211S | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV65841880, COSV65842407; called by muse, mutect2, varscan2
- OR10G2 | c.538G>A p.D180N | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT tolerated (0.07); PolyPhen benign (0.041); catalogued as COSV73390424; called by muse, varscan2
- OR10G9 | c.656C>T p.S219F | Missense Mutation (SNP) | VAF 37/75 reads (49%) | SIFT tolerated (0.7); PolyPhen benign (0.167); catalogued as COSV100901472; called by muse, mutect2, varscan2
- OR10H3 | c.343C>T p.L115F | Missense Mutation (SNP) | VAF 85/246 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1229355322, COSV100008295; called by muse, mutect2, varscan2
- OR10H5 | c.311C>T p.S104F | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT tolerated (1); PolyPhen benign (0.078); catalogued as COSV58279429; called by muse, mutect2, varscan2
- OR11L1 | c.790C>T p.P264S | Missense Mutation (SNP) | VAF 14/81 reads (17%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as COSV63315752; called by muse, mutect2, varscan2
- OR13C3 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 34/107 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV66165629; called by muse, mutect2, varscan2
- OR1D2 | c.515G>A p.R172Q | Missense Mutation (SNP) | VAF 12/43 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.028); catalogued as rs767444459, COSV58921027; called by muse, mutect2, varscan2
- OR1J1 | c.172C>T p.P58S | Missense Mutation (SNP) | VAF 32/125 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.97); catalogued as rs764732792, COSV99403075; called by muse, mutect2, varscan2
- OR1L3 | c.730C>T p.H244Y | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen benign (0.191); catalogued as rs1224510486, COSV100506195, COSV100506217; called by muse, mutect2, varscan2
- OR1Q1 | c.555G>A p.M185I | Missense Mutation (SNP) | VAF 43/125 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.069); catalogued as COSV99939171; called by muse, mutect2, varscan2
- OR2A5 | c.346G>A p.V116I | Missense Mutation (SNP) | VAF 120/233 reads (52%) | SIFT deleterious (0.02); PolyPhen benign (0.191); catalogued as COSV101278665, COSV68738867; called by muse, mutect2, varscan2
- OR2F2 | c.4G>A p.E2K | Missense Mutation (SNP) | VAF 45/98 reads (46%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as COSV101283795; called by muse, mutect2, varscan2
- OR2T11 | c.577G>A p.E193K | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.1); PolyPhen benign (0.391); catalogued as COSV58185321; called by muse, mutect2, varscan2
- OR2T33 | c.511G>A p.E171K | Missense Mutation (SNP) | VAF 12/35 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.477); catalogued as rs1341758711, COSV58816981, COSV58817423; called by muse, mutect2, varscan2
- OR2T33 | c.334C>T p.L112F | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.32); catalogued as COSV100531585; called by muse, varscan2
- OR2W3 | c.224C>T p.T75I | Missense Mutation (SNP) | VAF 32/159 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as COSV100831588, COSV64457532; called by muse, mutect2, varscan2
- OR4C16 | c.581A>G p.N194S | Missense Mutation (SNP) | VAF 32/129 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.764); catalogued as COSV100113834; called by muse, mutect2, varscan2
- OR4C46 | c.402G>A p.M134I | Missense Mutation (SNP) | VAF 39/130 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.559); catalogued as rs751021328, COSV60218178; called by muse, mutect2, varscan2
- OR4D2 | c.747G>A p.M249I | Missense Mutation (SNP) | VAF 39/150 reads (26%) | SIFT tolerated (0.11); PolyPhen benign (0.142); catalogued as COSV73459867; called by muse, mutect2, varscan2
- OR4D5 | c.278C>T p.S93F | Missense Mutation (SNP) | VAF 30/68 reads (44%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.452); catalogued as COSV58307045; called by muse, mutect2, varscan2
- OR4D5 | c.650C>T p.S217L | Missense Mutation (SNP) | VAF 63/142 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs138187932; called by muse, mutect2, varscan2
- OR4K1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 34/106 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.898); catalogued as rs149331048, COSV53458632, COSV53459042; called by muse, mutect2, varscan2
- OR4K13 | c.158C>T p.S53L | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT tolerated (0.29); PolyPhen benign (0.02); catalogued as rs202203700, COSV59859121; called by muse, mutect2, varscan2
- OR51A4 | c.322G>A p.G108R | Missense Mutation (SNP) | VAF 54/343 reads (16%) | SIFT tolerated (0.25); PolyPhen benign (0.151); catalogued as rs750620171, COSV66749436; called by muse, mutect2, varscan2
- OR51M1 | c.934C>T p.H312Y | Missense Mutation (SNP) | VAF 6/31 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.038); catalogued as COSV100150122; called by muse, mutect2
- OR52A5 | c.710G>A p.R237Q | Missense Mutation (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.938); catalogued as COSV56614860; called by muse, mutect2, varscan2
- OR52E4 | c.458G>A p.R153K | Missense Mutation (SNP) | VAF 28/103 reads (27%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.458); catalogued as rs754577619, COSV100389136, COSV100389305; called by muse, mutect2, varscan2
- OR52E6 | c.655C>T p.H219Y | Missense Mutation (SNP) | VAF 17/53 reads (32%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV61433064; called by muse, mutect2, varscan2
- OR56A1 | c.271G>A p.D91N | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.033); catalogued as COSV57361987; called by muse, mutect2, varscan2
- OR56B1 | c.887A>G p.N296S | Missense Mutation (SNP) | VAF 78/281 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1161356184, COSV100402531; called by muse, mutect2, varscan2
- OR5AC2 | c.382A>T p.I128L | Missense Mutation (SNP) | VAF 64/341 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100684289; called by muse, mutect2, varscan2
- OR5J2 | c.40C>T p.L14F | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.894); catalogued as rs1393952421, COSV100398901; called by muse, varscan2
- OR5T1 | c.400C>T p.R134C | Missense Mutation (SNP) | VAF 57/198 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.082); catalogued as rs371059328, COSV57302248; called by muse, mutect2, varscan2
- OR5T3 | c.817A>G p.R273G | Missense Mutation (SNP) | VAF 38/125 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.168); catalogued as COSV100282671; called by muse, mutect2, varscan2
- OR8D2 | c.919G>A p.G307R | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100658889; called by muse, mutect2, varscan2
- OR8K3 | c.99G>A p.M33I | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100449651; called by muse, mutect2, varscan2
- OR8U1 | c.569C>T p.S190L | Missense Mutation (SNP) | VAF 32/257 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.4); catalogued as rs766677267, COSV100163765; called by muse, mutect2
- ORC3 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1394807406, COSV100005605; called by muse, mutect2, varscan2
- OTULINL | c.823G>A p.E275K | Missense Mutation (SNP) | VAF 43/143 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.6); catalogued as COSV99947036; called by muse, mutect2, varscan2
- P4HA3 | c.647G>A p.G216E | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV59044462; called by muse, mutect2, varscan2
- PAGE2 | c.103G>A p.E35K | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.995); catalogued as COSV66596212; called by muse, mutect2, varscan2
- PAK3 | c.1537C>T p.R513C (on ENST00000262836 / NM_001324328.2; = p.R498C on NM_002578.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/77 reads (53%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as rs777234110, COSV53273344; called by muse, mutect2, varscan2
- PAK5 | c.1463G>A p.R488Q | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs958970085, COSV100781207, COSV62032194; called by muse, mutect2, varscan2
- PALLD | c.606T>G p.S202R | Missense Mutation (SNP) | VAF 58/145 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99823835; called by muse, mutect2, varscan2
- PAM | c.2912C>T p.S971F (on ENST00000438793 / NM_001319943.1; = p.S972F on NM_000919.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.206); catalogued as rs747469558, COSV99173043; called by muse, mutect2, varscan2
- PAPPA | c.4297C>T p.Q1433* | Nonsense Mutation (SNP) | VAF 17/74 reads (23%) | catalogued as rs751435846, COSV100072849; called by muse, mutect2, varscan2
- PAPPA2 | c.1873G>A p.D625N | Missense Mutation (SNP) | VAF 35/66 reads (53%) | SIFT tolerated (0.52); PolyPhen benign (0.124); catalogued as COSV62778375, COSV62782699; called by muse, mutect2, varscan2
- PAPPA2 | c.3730G>A p.E1244K | Missense Mutation (SNP) | VAF 40/142 reads (28%) | SIFT tolerated (0.96); PolyPhen benign (0); catalogued as COSV62807676; called by muse, mutect2, varscan2
- PAPPA2 | c.3875A>G p.H1292R | Missense Mutation (SNP) | VAF 50/90 reads (56%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV100867561; called by muse, mutect2, varscan2
- PARD3B | c.3277C>T p.P1093S (on ENST00000406610 / NM_001302769.2; = p.P1024S on NM_057177.7) | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.11); catalogued as COSV62519313; called by muse, mutect2, varscan2
- PARM1 | c.224C>T p.S75F | Missense Mutation (SNP) | VAF 24/78 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.735); catalogued as rs370099487; called by muse, mutect2, varscan2
- PARP12 | c.1811C>T p.S604F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as COSV99693806; called by muse, mutect2, varscan2
- PAX7 | c.118C>T p.Q40* | Nonsense Mutation (SNP) | VAF 17/22 reads (77%) | catalogued as COSV100946557; called by muse, mutect2, varscan2
- PCARE | c.532G>A p.E178K | Missense Mutation (SNP) | VAF 24/87 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as COSV59055328, COSV59058799; called by muse, mutect2, varscan2
- PCDH8 | c.3116G>A p.G1039E | Missense Mutation (SNP) | VAF 27/124 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.136); catalogued as COSV100131194, COSV58814448; called by muse, mutect2, varscan2
- PCDHA1 | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 19/73 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100974259; called by muse, mutect2, varscan2
- PCDHA11 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 18/92 reads (20%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.279); catalogued as rs1554164938, COSV56475711, COSV56484997; called by muse, mutect2, varscan2
- PCDHA11 | c.1859C>T p.P620L | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.03); catalogued as rs1489353896, COSV100247575, COSV100248534; called by muse, mutect2, varscan2
- PCDHA4 | c.1888G>A p.E630K | Missense Mutation (SNP) | VAF 40/137 reads (29%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.997); catalogued as COSV63540878; called by muse, mutect2, varscan2
- PCDHA5 | c.1820C>T p.S607L | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated, low confidence (0.05); PolyPhen possibly damaging (0.87); catalogued as rs868924111, COSV65349820; called by muse, mutect2, varscan2
- PCDHA9 | c.925G>A p.D309N | Missense Mutation (SNP) | VAF 14/46 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV65327070; called by muse, mutect2, varscan2
- PCDHAC1 | c.2594G>A p.G865E | Missense Mutation (SNP) | VAF 27/82 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.969); catalogued as COSV99144298, COSV99145080; called by muse, mutect2, varscan2
- PCDHGA3 | c.1127C>T p.S376F | Missense Mutation (SNP) | VAF 37/115 reads (32%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.429); catalogued as COSV99530561; called by muse, mutect2, varscan2
- PCDHGA4 | c.2359G>A p.E787K | Missense Mutation (SNP) | VAF 37/119 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV99529110, COSV99530563; called by muse, mutect2, varscan2
- PCDHGA6 | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 28/112 reads (25%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.049); catalogued as COSV99530565; called by muse, mutect2, varscan2
- PCLO | c.14393C>T p.S4798L | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV100427364, COSV61626787, COSV61652870; called by muse, mutect2, varscan2
- PCOLCE2 | c.571C>T p.Q191* | Nonsense Mutation (SNP) | VAF 38/75 reads (51%) | catalogued as COSV99930368; called by muse, mutect2, varscan2
- PDCD7 | c.1332C>T p.I444= | Splice Region (SNP) | VAF 4/27 reads (15%) | catalogued as COSV52600901; called by muse, mutect2
- PDE1C | c.940G>A p.E314K | Missense Mutation (SNP) | VAF 19/109 reads (17%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.614); catalogued as COSV100373567, COSV58506661; called by muse, mutect2, varscan2
- PDE6B | c.872C>T p.S291F | Missense Mutation (SNP) | VAF 24/74 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.485); catalogued as rs1560118465, COSV99726907; called by muse, mutect2, varscan2
- PDZD2 | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 30/87 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs774955972, COSV99223650; called by muse, mutect2, varscan2
- PEMT | c.337T>C p.F113L | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.761); catalogued as COSV99702905; called by muse, mutect2
- PENK | c.80G>A p.S27N | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.19); PolyPhen benign (0.438); catalogued as COSV100152156; called by muse, mutect2, varscan2
- PER2 | c.1156C>T p.L386= | Splice Region (SNP) | VAF 26/64 reads (41%) | catalogued as COSV99611424; called by muse, mutect2, varscan2
- PGAP6 | c.1912C>T p.L638F | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.691); catalogued as rs767554044, COSV99170577; called by muse, mutect2, varscan2
- PGD | c.970C>T p.R324W | Missense Mutation (SNP) | VAF 54/102 reads (53%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs756735573, COSV54621455, COSV54622307; called by muse, varscan2
- PHF20L1 | c.1547T>C p.I516T | Missense Mutation (SNP) | VAF 8/30 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.025); catalogued as rs1013380374, COSV99620328; called by muse, mutect2, varscan2
- PI15 | c.751T>A p.S251T | Missense Mutation (SNP) | VAF 27/100 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.009); catalogued as COSV99477789; called by muse, mutect2, varscan2
- PID1 | c.334G>A p.E112K (on ENST00000354069 / NM_001330156.1; = p.E110K on NM_017933.5) | Missense Mutation (SNP) | VAF 32/71 reads (45%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.995); catalogued as rs867123602, COSV100819535; called by muse, mutect2, varscan2
- PITPNM1 | c.2225C>T p.P742L | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1251380973, COSV100711544; called by muse, mutect2, varscan2
- PITPNM1 | c.2224C>T p.P742S | Missense Mutation (SNP) | VAF 5/39 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1439590139, COSV100711546; called by muse, mutect2, varscan2
- PITPNM1 | c.1092C>A p.F364L | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.2); PolyPhen benign (0.02); catalogued as COSV100711547; called by muse, mutect2, varscan2
- PKHD1 | c.11753G>A p.G3918E | Missense Mutation (SNP) | VAF 33/161 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1342490981, COSV100943678; called by muse, mutect2, varscan2
- PKHD1L1 | c.2495G>A p.G832E | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.313); catalogued as rs1354063817, COSV101005354; called by muse, mutect2, varscan2
- PKHD1L1 | c.10289G>A p.G3430E | Missense Mutation (SNP) | VAF 5/18 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV65753754; called by muse, mutect2, varscan2
- PKHD1L1 | c.12047C>T p.S4016F | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.472); catalogued as COSV101005357; called by muse, mutect2, varscan2
- PLA2G4E | c.1477G>A p.E493K | Missense Mutation (SNP) | VAF 75/170 reads (44%) | SIFT tolerated (0.64); PolyPhen benign (0.043); catalogued as rs538654633, COSV101268518; called by muse, mutect2, varscan2
- PLA2R1 | c.386C>T p.S129F | Missense Mutation (SNP) | VAF 69/138 reads (50%) | SIFT deleterious (0.02); PolyPhen benign (0.025); catalogued as rs140862370, COSV51787491; called by muse, mutect2, varscan2
- PLCB1 | c.146G>A p.G49E | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.883); catalogued as rs1412123237, COSV62043464; called by muse, mutect2, varscan2
- PLCB1 | c.2860G>A p.E954K | Missense Mutation (SNP) | VAF 31/92 reads (34%) | SIFT tolerated (0.21); PolyPhen benign (0.006); catalogued as COSV100569331; called by muse, mutect2, varscan2
- PLCB4 | c.725T>C p.L242S | Missense Mutation (SNP) | VAF 20/78 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.8); catalogued as rs1167130906, COSV99594348; called by muse, mutect2, varscan2
- PLCB4 | c.3037-1G>A p.X1013_splice | Splice Site (SNP) | VAF 9/27 reads (33%) | catalogued as rs1399127325, COSV99594350; called by muse, mutect2, varscan2
- PLCB4 | c.3244A>G p.K1082E | Missense Mutation (SNP) | VAF 43/160 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV99594353; called by muse, mutect2, varscan2
- PLCH1 | c.3932C>T p.S1311F (on ENST00000340059 / NM_001130960.2; = p.S1303F on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 88/210 reads (42%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs370282412; called by muse, mutect2, varscan2
- PLCH1 | c.1516G>A p.D506N (on ENST00000340059 / NM_001130960.2; = p.D518N on NM_014996.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100395549; called by muse, mutect2, varscan2
- PLD4 | c.833G>A p.W278* | Nonsense Mutation (SNP) | VAF 46/127 reads (36%) | catalogued as COSV101190449; called by muse, mutect2, varscan2
- PLG | c.878G>A p.G293E | Missense Mutation (SNP) | VAF 31/113 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV99804235; called by muse, mutect2, varscan2
- PLPPR1 | c.302C>T p.S101F | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT deleterious (0.05); PolyPhen benign (0.029); catalogued as rs866615719, COSV100883015; called by muse, mutect2, varscan2
- PLXDC2 | c.257C>T p.S86F | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.641); catalogued as rs777126319, COSV65919121; called by muse, mutect2, varscan2
- PLXDC2 | c.356G>A p.R119Q | Missense Mutation (SNP) | VAF 43/163 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.174); catalogued as rs867172280, COSV65903483; called by muse, mutect2, varscan2
976 further variants in this file (358 protein-altering or splice-affecting, 574 silent, 44 other) are not listed here.
